Somatic mutation profile of tumor specimen TCGA-44-2656-01A (aliquot TCGA-44-2656-01A-02D-0969-08) from TCGA case TCGA-44-2656, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 59.6 years (21,766 days).
Specimen TCGA-44-2656-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3dd81d97-d573-4c22-b9a6-87304f937c86.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-44-2656-10A (Blood Derived Normal), aliquot TCGA-44-2656-10A-01D-0969-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5d72331e-bf31-49b2-9564-0f64dac55943

The open-access MAF lists 941 somatic variants for this specimen: 725 protein-altering or splice-affecting, 199 silent, 17 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 601, Silent 199, Nonsense Mutation 62, Splice Site 26, Frame Shift Del 17, Splice Region 10, Intron 7, Frame Shift Ins 6, RNA 5, 5'UTR 2, 3'UTR 2, In Frame Del 1.

Variants (750 of 941; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ERBB2 | c.929C>T p.S310F | Missense Mutation (SNP) | VAF 174/562 reads (31%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1057519816, COSV54062198, COSV54062802; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- A1CF | c.778G>C p.E260Q | Missense Mutation (SNP) | VAF 13/122 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.11); catalogued as COSV50957947; called by muse, mutect2, varscan2
- AADACL2 | c.786G>A p.W262* | Nonsense Mutation (SNP) | VAF 76/285 reads (27%) | catalogued as COSV62929677; called by muse, mutect2, varscan2
- ABCA10 | c.3577G>T p.E1193* | Nonsense Mutation (SNP) | VAF 31/110 reads (28%) | catalogued as COSV52218722; called by muse, mutect2, varscan2
- ABCA13 | c.12366G>T p.K4122N | Missense Mutation (SNP) | VAF 36/210 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); catalogued as COSV71284197; called by muse, mutect2, varscan2
- ABCA4 | c.426C>A p.H142Q | Missense Mutation (SNP) | VAF 46/196 reads (23%) | SIFT tolerated (0.41); PolyPhen benign (0.009); catalogued as COSV64671523; called by muse, mutect2, varscan2
- ABCA9 | c.661G>T p.V221F | Missense Mutation (SNP) | VAF 41/205 reads (20%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV60621424, COSV60627170; called by muse, mutect2, varscan2
- ABCC9 | c.52G>C p.G18R | Missense Mutation (SNP) | VAF 24/100 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.883); catalogued as COSV53964291; called by muse, mutect2, varscan2
- AC105001.2 | c.178G>T p.V60L | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.121); catalogued as COSV59108476; called by muse, mutect2, varscan2
- ACSL1 | c.724G>T p.G242W | Missense Mutation (SNP) | VAF 40/246 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55661049, COSV55666266; called by muse, mutect2, varscan2
- ACTG1 | c.136G>T p.G46C | Missense Mutation (SNP) | VAF 58/201 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.745); catalogued as COSV59509545, COSV59509810; called by muse, varscan2
- ADAM12 | c.1436G>T p.G479V | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64103177, COSV64103261; called by muse, mutect2
- ADAM20 | c.285G>T p.Q95H | Missense Mutation (SNP) | VAF 28/175 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.71); catalogued as COSV56454240; called by muse, mutect2, varscan2
- ADAMTS15 | c.1726G>A p.G576R | Missense Mutation (SNP) | VAF 39/773 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs147190472; called by muse, mutect2
- ADAMTS16 | c.3591C>A p.C1197* | Nonsense Mutation (SNP) | VAF 28/77 reads (36%) | catalogued as COSV56980510; called by muse, mutect2, varscan2
- ADCY5 | c.1909A>T p.I637F | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV59194995; called by muse, mutect2, varscan2
- ADCY6 | c.1495G>T p.V499L | Missense Mutation (SNP) | VAF 50/115 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57166513; called by muse, mutect2, varscan2
- ADGRG4 | c.3931C>T p.Q1311* | Nonsense Mutation (SNP) | VAF 41/129 reads (32%) | catalogued as rs1433246655, COSV54950883; called by muse, mutect2, varscan2
- ADGRL4 | c.844T>A p.F282I | Missense Mutation (SNP) | VAF 31/262 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV66059758; called by muse, mutect2, varscan2
- AFF2 | c.631G>T p.E211* | Nonsense Mutation (SNP) | VAF 140/305 reads (46%) | catalogued as COSV60656743, COSV60659025; called by muse, mutect2, varscan2
- AFF4 | c.400C>T p.Q134* | Nonsense Mutation (SNP) | VAF 33/107 reads (31%) | catalogued as COSV54792178; called by muse, mutect2, varscan2
- AGAP1 | c.479G>T p.S160I | Missense Mutation (SNP) | VAF 8/136 reads (6%) | SIFT tolerated (0.16); PolyPhen benign (0.142); catalogued as rs1463385072, COSV58318767; called by muse, mutect2
- AGL | c.790G>T p.G264W | Missense Mutation (SNP) | VAF 26/128 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54048722, COSV54054032; called by muse, mutect2, varscan2
- AGO3 | c.399G>T p.W133C | Missense Mutation (SNP) | VAF 16/122 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.497); catalogued as COSV55791675; called by muse, mutect2, varscan2
- AHNAK2 | c.16357C>A p.L5453M | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.906); catalogued as COSV60909238; called by muse, mutect2, varscan2
- AHNAK2 | c.14074G>A p.E4692K | Missense Mutation (SNP) | VAF 15/121 reads (12%) | SIFT tolerated (0.61); PolyPhen benign (0.001); catalogued as COSV60909243; called by muse, mutect2, varscan2
- AHNAK2 | c.2839G>T p.G947C | Missense Mutation (SNP) | VAF 94/550 reads (17%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.998); catalogued as COSV60909246; called by muse, mutect2, varscan2
- ALDH1L1 | c.1480G>T p.D494Y | Missense Mutation (SNP) | VAF 40/124 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV56411309; called by muse, mutect2, varscan2
- ALK | c.1359G>T p.Q453H | Missense Mutation (SNP) | VAF 23/167 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.713); catalogued as COSV66559553; called by muse, mutect2, varscan2
- ALOX5 | c.437T>A p.M146K | Missense Mutation (SNP) | VAF 12/136 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV65551322; called by muse, mutect2
- ALPK2 | c.3485C>A p.A1162D | Missense Mutation (SNP) | VAF 68/272 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.083); catalogued as COSV100864754, COSV64490735; called by muse, mutect2
- ALPK2 | c.884C>G p.P295R | Missense Mutation (SNP) | VAF 16/148 reads (11%) | SIFT tolerated (0.35); PolyPhen benign (0.101); catalogued as COSV64490743; called by muse, mutect2, varscan2
- AMPD2 | c.442G>T p.E148* | Nonsense Mutation (SNP) | VAF 11/74 reads (15%) | catalogued as COSV56646529; called by muse, mutect2, varscan2
- AP2A2 | c.2555A>T p.Q852L | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV59958409; called by muse, mutect2, varscan2
- APBB1 | c.1382G>A p.R461K | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.059); catalogued as COSV54973374; called by muse, mutect2
- APIP | c.57G>T p.Q19H | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV53506143; called by muse, mutect2, varscan2
- APOB | c.2617C>A p.L873M | Missense Mutation (SNP) | VAF 24/171 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV51925712; called by muse, mutect2, varscan2
- APOBEC4 | c.41C>T p.T14I | Missense Mutation (SNP) | VAF 36/201 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58016983; called by muse, mutect2, varscan2
- APOBR | c.2839G>T p.A947S (on ENST00000431282; = p.A956S on NM_018690.4) | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as rs1486024392, COSV60489064; called by muse, mutect2, varscan2
- ARFIP1 | c.567G>T p.M189I (on ENST00000353617 / NM_001287432.1; = p.M157I on NM_014447.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 46/240 reads (19%) | SIFT tolerated (0.32); PolyPhen benign (0.017); catalogued as COSV61883385, COSV61886434; called by muse, mutect2, varscan2
- ARHGAP25 | c.1380C>A p.S460R (on ENST00000409202 / NM_001007231.3; = p.S452R on NM_014882.3) | Missense Mutation (SNP) | VAF 37/233 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.348); catalogued as COSV54899273; called by muse, mutect2, varscan2
- ARHGAP33 | c.1814G>A p.R605Q | Missense Mutation (SNP) | VAF 33/107 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.648); catalogued as rs139022184; called by muse, mutect2, varscan2
- ARMC5 | c.356C>T p.P119L | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as COSV51655112; called by muse, mutect2, varscan2
- ARMC5 | c.1085G>C p.R362P | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51655120, COSV51659726; called by muse, mutect2, varscan2
- ARSF | c.746G>C p.R249P | Missense Mutation (SNP) | VAF 30/97 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63839074; called by muse, mutect2, varscan2
- ASB15 | c.323C>A p.T108N | Missense Mutation (SNP) | VAF 71/240 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.914); catalogued as COSV99306291; called by muse, mutect2, varscan2
- ASPM | c.8315A>G p.Q2772R | Missense Mutation (SNP) | VAF 37/308 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as COSV54125763; called by muse, mutect2, varscan2
- ASTL | c.216C>G p.F72L | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.525); catalogued as COSV60903665; called by muse, mutect2, varscan2
- ASXL3 | c.3416C>A p.P1139H | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.007); catalogued as COSV99323798; called by muse, mutect2, varscan2
- ATP13A2 | c.3034G>T p.V1012L | Missense Mutation (SNP) | VAF 34/104 reads (33%) | SIFT tolerated (0.65); PolyPhen benign (0.046); catalogued as COSV58698526; called by muse, mutect2, varscan2
- ATP1A3 | c.2892G>T p.E964D (on ENST00000545399 / NM_001256214.2; = p.E951D on NM_152296.5) | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.191); catalogued as COSV57485662; called by muse, mutect2, varscan2
- ATP1B4 | c.844A>G p.I282V (on ENST00000218008 / NM_001142447.3; = p.I278V on NM_012069.5) | Missense Mutation (SNP) | VAF 126/292 reads (43%) | SIFT tolerated (0.72); PolyPhen benign (0.02); catalogued as COSV54311501; called by muse, mutect2, varscan2
- ATP2A1 | c.875C>T p.A292V | Missense Mutation (SNP) | VAF 28/275 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.058); catalogued as COSV63920115; called by muse, mutect2, varscan2
- ATP2B3 | c.1206G>A p.W402* | Nonsense Mutation (SNP) | VAF 14/111 reads (13%) | catalogued as COSV54841452; called by muse, mutect2, varscan2
- ATXN1 | c.490G>T p.G164W | Missense Mutation (SNP) | VAF 40/122 reads (33%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.647); catalogued as COSV55207197, COSV55209691; called by muse, mutect2, varscan2
- BABAM2 | c.851+1G>T p.X284_splice | Splice Site (SNP) | VAF 19/119 reads (16%) | catalogued as COSV59617839, COSV59626067; called by muse, mutect2, varscan2
- BCAS1 | c.1153G>C p.D385H | Missense Mutation (SNP) | VAF 15/118 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV65084225; called by muse, mutect2, varscan2
- BCAS1 | c.811G>T p.A271S | Missense Mutation (SNP) | VAF 38/153 reads (25%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.669); catalogued as COSV65084231; called by muse, mutect2, varscan2
- BICD1 | c.193G>C p.E65Q | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV55675492, COSV55683113; called by muse, mutect2, varscan2
- BIN2 | c.745G>C p.V249L | Missense Mutation (SNP) | VAF 122/357 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.213); catalogued as COSV57203914; called by muse, mutect2, varscan2
- BLOC1S4 | c.506C>T p.A169V | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.371); catalogued as COSV57900861, COSV57901018; called by muse, mutect2, varscan2
- BORA | c.853T>A p.S285T (on ENST00000613797; = p.S210T on NM_024808.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 52/356 reads (15%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.709); catalogued as COSV64694931; called by muse, mutect2, varscan2
- BRAT1 | c.881A>G p.H294R | Missense Mutation (SNP) | VAF 28/170 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.038); catalogued as COSV61394381; called by muse, mutect2, varscan2
- BRINP3 | c.2026G>C p.D676H | Missense Mutation (SNP) | VAF 64/312 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV66515010; called by muse, mutect2, varscan2
- BRIP1 | c.3601A>G p.I1201V | Missense Mutation (SNP) | VAF 41/122 reads (34%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.003); catalogued as rs1396175226, COSV51994991; called by muse, mutect2, varscan2
- BUB1B | c.388C>T p.R130C | Missense Mutation (SNP) | VAF 44/143 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as rs587778144, COSV55010377; ClinVar: not provided; called by muse, mutect2, varscan2
- C1orf116 | c.1667C>A p.S556Y | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); catalogued as COSV63943796; called by muse, mutect2
- C22orf42 | c.295C>A p.L99I | Missense Mutation (SNP) | VAF 62/229 reads (27%) | SIFT tolerated, low confidence (0.51); PolyPhen possibly damaging (0.567); catalogued as COSV66075359; called by muse, mutect2, varscan2
- C2orf78 | c.1831C>A p.Q611K | Missense Mutation (SNP) | VAF 34/110 reads (31%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.52); catalogued as COSV68516564; called by muse, mutect2, varscan2
- C8B | c.1119C>A p.N373K | Missense Mutation (SNP) | VAF 19/167 reads (11%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as COSV64776652; called by muse, mutect2, varscan2
- C9orf64 | c.490G>T p.G164* | Nonsense Mutation (SNP) | VAF 52/203 reads (26%) | catalogued as COSV59032188; called by muse, mutect2, varscan2
- CACNA1E | c.1924A>C p.T642P | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62384172; called by muse, mutect2, varscan2
- CACNA1E | c.5791G>T p.G1931C | Missense Mutation (SNP) | VAF 23/130 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.043); catalogued as COSV62383371, COSV62384187; called by muse, varscan2
- CACNA2D3 | c.1492G>T p.G498* | Nonsense Mutation (SNP) | VAF 20/280 reads (7%) | catalogued as rs748252575, COSV55518993; called by muse, mutect2
- CADPS | c.1137C>G p.I379M | Missense Mutation (SNP) | VAF 42/228 reads (18%) | SIFT tolerated (0.38); PolyPhen benign (0.011); catalogued as COSV51869717; called by muse, mutect2, varscan2
- CALU | c.332G>T p.R111L | Missense Mutation (SNP) | VAF 41/132 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.142); catalogued as COSV50823286, COSV99975725; called by muse, mutect2, varscan2
- CAMK2A | c.158-1G>T p.X53_splice | Splice Site (SNP) | VAF 17/99 reads (17%) | catalogued as COSV62245306; called by muse, mutect2, varscan2
- CAMK4 | c.452C>A p.A151E | Missense Mutation (SNP) | VAF 24/131 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56663808; called by muse, mutect2, varscan2
- CAMTA1 | c.599A>G p.N200S | Missense Mutation (SNP) | VAF 7/196 reads (4%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.93); catalogued as rs1335374168, COSV57884758; called by muse, mutect2
- CARD11 | c.258G>T p.R86S | Missense Mutation (SNP) | VAF 80/578 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV62716163, COSV62716582; called by muse, mutect2, varscan2
- CARMIL2 | c.521G>A p.R174Q | Missense Mutation (SNP) | VAF 27/254 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as rs201242195, COSV58023678; called by muse, mutect2, varscan2
- CARMIL2 | c.544G>T p.D182Y | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100575991; called by muse, mutect2
- CCDC136 | c.1894C>A p.Q632K | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV52796854; called by muse, mutect2, varscan2
- CCDC171 | c.2564A>C p.K855T | Missense Mutation (SNP) | VAF 101/381 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV52634882; called by muse, mutect2, varscan2
- CCDC63 | c.1222G>T p.D408Y | Missense Mutation (SNP) | VAF 81/173 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.748); catalogued as COSV57527263; called by muse, mutect2, varscan2
- CCDC9B | c.998G>A p.R333K | Missense Mutation (SNP) | VAF 18/216 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV66874819; called by muse, mutect2
- CCNO | c.1027T>C p.C343R | Missense Mutation (SNP) | VAF 30/126 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.526); catalogued as rs750464287, COSV57004411; called by muse, mutect2, varscan2
- CCT8L2 | c.1539G>C p.Q513H | Missense Mutation (SNP) | VAF 111/316 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.381); catalogued as COSV63461753, COSV63464025; called by muse, mutect2, varscan2
- CD163 | c.2960G>T p.G987V | Missense Mutation (SNP) | VAF 25/151 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100775730, COSV63131323; called by muse, mutect2, varscan2
- CD163 | c.2959G>T p.G987W | Missense Mutation (SNP) | VAF 25/152 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100775731; called by muse, mutect2, varscan2
- CD244 | c.785C>A p.T262N (on ENST00000368033 / NM_001166663.2; = p.T257N on NM_016382.4) | Missense Mutation (SNP) | VAF 41/244 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.222); catalogued as rs1377239214, COSV59236441; called by muse, mutect2, varscan2
- CD244 | c.403G>T p.E135* (on ENST00000368033 / NM_001166663.2; = p.E130* on NM_016382.4) | Nonsense Mutation (SNP) | VAF 42/169 reads (25%) | catalogued as COSV59236463, COSV59237862; called by muse, mutect2, varscan2
- CD5L | c.895A>T p.K299* | Nonsense Mutation (SNP) | VAF 85/320 reads (27%) | catalogued as COSV63821247; called by muse, mutect2, varscan2
- CD6 | c.1364T>C p.V455A | Missense Mutation (SNP) | VAF 8/160 reads (5%) | SIFT tolerated (0.17); PolyPhen benign (0.232); catalogued as COSV57836214; called by muse, mutect2
- CDH1 | c.1378G>T p.V460L | Missense Mutation (SNP) | VAF 34/170 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.013); catalogued as COSV55728592; called by muse, mutect2, varscan2
- CDH12 | c.1456C>T p.P486S | Missense Mutation (SNP) | VAF 16/290 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV66390889; called by muse, mutect2
- CDH6 | c.613C>G p.Q205E | Missense Mutation (SNP) | VAF 14/284 reads (5%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.874); catalogued as COSV54065290; called by muse, mutect2
- CEACAM18 | c.682G>C p.D228H | Missense Mutation (SNP) | VAF 106/347 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV67282317, COSV67283582; called by muse, mutect2, varscan2
- CEP126 | c.15G>T p.R5S | Missense Mutation (SNP) | VAF 59/167 reads (35%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.668); catalogued as COSV54822265; called by muse, mutect2, varscan2
- CFAP299 | c.601C>A p.P201T | Missense Mutation (SNP) | VAF 33/174 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63871884; called by muse, mutect2, varscan2
- CFAP57 | c.133C>A p.Q45K | Missense Mutation (SNP) | VAF 39/162 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.131); catalogued as COSV52539439; called by muse, mutect2, varscan2
- CFHR4 | c.249C>A p.C83* (on ENST00000367416 / NM_001201551.2; = p.C84* on NM_006684.5) | Nonsense Mutation (SNP) | VAF 75/282 reads (27%) | catalogued as COSV52225316; called by muse, mutect2, varscan2
- CFHR5 | c.1145C>A p.T382K | Missense Mutation (SNP) | VAF 18/108 reads (17%) | SIFT tolerated (0.66); PolyPhen benign (0.007); catalogued as COSV56818614; called by muse, mutect2, varscan2
- CHST13 | c.137G>C p.G46A | Missense Mutation (SNP) | VAF 64/247 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.473); catalogued as COSV60041502; called by muse, mutect2, varscan2
- CHST2 | c.895C>G p.R299G | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as COSV58884824; called by muse, mutect2, varscan2
- CIB4 | c.197T>A p.F66Y | Missense Mutation (SNP) | VAF 17/102 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56599510; called by muse, mutect2, varscan2
- CIP2A | c.1924G>T p.D642Y | Missense Mutation (SNP) | VAF 24/105 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55417434; called by muse, mutect2, varscan2
- CIT | c.841G>T p.G281C | Missense Mutation (SNP) | VAF 85/222 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); catalogued as COSV55861941; called by muse, mutect2, varscan2
- CLASP1 | c.4265A>T p.Q1422L | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT tolerated (0.23); PolyPhen benign (0.034); catalogued as COSV55315566; called by muse, mutect2, varscan2
- CLCN4 | c.1016G>C p.G339A | Missense Mutation (SNP) | VAF 11/270 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66465375; called by muse, mutect2
- CLDN14 | c.414G>T p.W138C | Missense Mutation (SNP) | VAF 23/170 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59772018; called by muse, mutect2, varscan2
- CNGB3 | c.1179-1G>T p.X393_splice | Splice Site (SNP) | VAF 38/130 reads (29%) | catalogued as COSV60685706; called by muse, mutect2, varscan2
- CNTN2 | c.2914C>A p.P972T | Missense Mutation (SNP) | VAF 35/154 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.03); catalogued as COSV59348479; called by muse, mutect2, varscan2
- CNTN4 | c.631C>A p.P211T | Missense Mutation (SNP) | VAF 42/120 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.726); catalogued as COSV61868879; called by muse, mutect2, varscan2
- CNTNAP2 | c.1870C>A p.P624T | Missense Mutation (SNP) | VAF 86/265 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV62150646; called by muse, mutect2, varscan2
- CNTNAP4 | c.1150C>A p.P384T | Missense Mutation (SNP) | VAF 36/198 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as rs762920106, COSV100269809; called by muse, mutect2, varscan2
- CNTNAP4 | c.1151C>G p.P384R | Missense Mutation (SNP) | VAF 35/198 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.027); catalogued as COSV100269812; called by muse, mutect2, varscan2
- COBL | c.2142G>T p.K714N | Missense Mutation (SNP) | VAF 49/151 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV54339812; called by muse, mutect2, varscan2
- COL15A1 | c.3032-1G>T p.X1011_splice | Splice Site (SNP) | VAF 32/450 reads (7%) | catalogued as COSV66641776; called by muse, mutect2
- COL25A1 | c.602G>T p.G201V | Missense Mutation (SNP) | VAF 14/259 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67647040; called by muse, mutect2
- COL27A1 | c.3338C>T p.P1113L | Missense Mutation (SNP) | VAF 52/257 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.01); catalogued as COSV61922285; called by muse, mutect2, varscan2
- COL3A1 | c.282+1G>T p.X94_splice | Splice Site (SNP) | VAF 24/73 reads (33%) | catalogued as COSV58582976; called by muse, varscan2
- COL4A2 | c.2704G>T p.G902* | Nonsense Mutation (SNP) | VAF 28/145 reads (19%) | catalogued as COSV64625481; called by muse, mutect2, varscan2
- COL4A2 | c.4585C>A p.Q1529K | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100847267; called by mutect2, varscan2
- COL5A1 | c.1774G>T p.G592C | Missense Mutation (SNP) | VAF 57/149 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65665879; called by muse, mutect2, varscan2
- COL5A1 | c.2148G>T p.E716D | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.899); catalogued as COSV65665882; called by muse, mutect2, varscan2
- COL5A2 | c.3797C>T p.P1266L | Missense Mutation (SNP) | VAF 29/96 reads (30%) | SIFT tolerated (0.73); PolyPhen possibly damaging (0.781); catalogued as COSV100880708, COSV66407652; called by muse, mutect2, varscan2
- COL9A3 | c.1056C>A p.G352= | Splice Region (SNP) | VAF 4/27 reads (15%) | catalogued as COSV59650849; called by muse, mutect2
- CPEB1 | c.1621C>T p.Q541* (on ENST00000617958; = p.Q476* on NM_030594.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 30/107 reads (28%) | catalogued as COSV55617442; called by muse, mutect2, varscan2
- CPED1 | c.2839C>A p.Q947K | Missense Mutation (SNP) | VAF 87/309 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.754); catalogued as COSV100120269; called by muse, mutect2, varscan2
- CRACD | c.2737G>T p.A913S | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT tolerated (0.25); PolyPhen benign (0.033); catalogued as COSV51716175; called by muse, mutect2, varscan2
- CREB3L2 | c.494G>T p.G165V | Missense Mutation (SNP) | VAF 30/119 reads (25%) | SIFT tolerated (0.28); PolyPhen benign (0.086); catalogued as COSV57792636; called by muse, mutect2, varscan2
- CRISPLD1 | c.1231T>A p.S411T | Missense Mutation (SNP) | VAF 11/204 reads (5%) | SIFT tolerated (0.76); PolyPhen benign (0.003); catalogued as COSV51544994; called by muse, mutect2
- CRISPLD2 | c.998G>C p.R333P | Missense Mutation (SNP) | VAF 34/264 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52277138; called by muse, mutect2, varscan2
- CROT | c.1064G>T p.G355V | Missense Mutation (SNP) | VAF 39/98 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58973012; called by muse, mutect2, varscan2
- CSMD1 | c.6664G>T p.A2222S (on ENST00000520002; = p.A2221S on NM_033225.6) | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.992); catalogued as COSV59289735, COSV59300282; called by muse, mutect2, varscan2
- CSMD2 | c.9173G>T p.W3058L | Missense Mutation (SNP) | VAF 25/249 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV53885674; called by muse, mutect2, varscan2
- CSMD2 | c.1918G>T p.A640S | Missense Mutation (SNP) | VAF 18/213 reads (8%) | SIFT tolerated (0.8); PolyPhen benign (0.074); catalogued as COSV53885699, COSV53897184; called by muse, mutect2
- CSMD3 | c.10628G>T p.G3543V (on ENST00000297405 / NM_001363185.1; = p.G3374V on NM_052900.3) | Missense Mutation (SNP) | VAF 29/354 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV52115921, COSV99834043; called by muse, mutect2
- CSMD3 | c.4107A>T p.Q1369H (on ENST00000297405 / NM_001363185.1; = p.Q1265H on NM_052900.3) | Missense Mutation (SNP) | VAF 70/170 reads (41%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.981); catalogued as COSV52116030; called by muse, mutect2, varscan2
- CSMD3 | c.1116C>A p.S372R | Missense Mutation (SNP) | VAF 33/229 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV52116072; called by muse, mutect2, varscan2
- CSN3 | c.100G>C p.D34H | Missense Mutation (SNP) | VAF 28/169 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.613); catalogued as COSV59243600; called by muse, mutect2, varscan2
- CT83 | c.137C>A p.S46Y | Missense Mutation (SNP) | VAF 51/117 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.089); catalogued as COSV64140819; called by muse, mutect2, varscan2
- CTNNA2 | c.2154G>T p.M718I | Missense Mutation (SNP) | VAF 24/149 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as COSV100559222, COSV58138215; called by muse, mutect2, varscan2
- CTNND2 | c.1418G>T p.G473V | Missense Mutation (SNP) | VAF 35/144 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.051); catalogued as COSV58869546; called by muse, mutect2, varscan2
- CUBN | c.10429C>A p.P3477T | Missense Mutation (SNP) | VAF 58/213 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1468596216, COSV64709163; called by muse, mutect2, varscan2
- CYP4F3 | c.552G>T p.E184D | Missense Mutation (SNP) | VAF 25/97 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.022); catalogued as COSV55407556; called by muse, mutect2, varscan2
- DCAF8L1 | c.101C>A p.A34E | Missense Mutation (SNP) | VAF 26/45 reads (58%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); catalogued as COSV71595155; called by muse, mutect2, varscan2
- DCUN1D1 | c.295A>G p.S99G | Missense Mutation (SNP) | VAF 18/157 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.192); catalogued as COSV53043841; called by muse, mutect2, varscan2
- DDC | c.570G>T p.Q190H | Missense Mutation (SNP) | VAF 127/379 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.86); catalogued as COSV63564084; called by muse, mutect2, varscan2
- DEFB112 | c.271G>A p.D91N | Missense Mutation (SNP) | VAF 21/104 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.877); catalogued as COSV59182425; called by muse, mutect2, varscan2
- DENND1A | c.77G>T p.G26V | Missense Mutation (SNP) | VAF 19/148 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.065); catalogued as COSV65323094; called by muse, mutect2, varscan2
- DENND4B | c.3679G>C p.G1227R | Missense Mutation (SNP) | VAF 14/165 reads (8%) | SIFT tolerated (0.27); PolyPhen benign (0.063); catalogued as COSV63407470; called by muse, mutect2
- DEPDC7 | c.1263G>A p.K421= (on ENST00000241051 / NM_001077242.2; = p.K412= on NM_139160.2) | Splice Region (SNP) | VAF 59/237 reads (25%) | catalogued as COSV53806054; called by muse, mutect2, varscan2
- DGKB | c.2281G>T p.E761* | Nonsense Mutation (SNP) | VAF 154/490 reads (31%) | catalogued as COSV51765416; called by muse, mutect2, varscan2
- DIO2 | c.512C>A p.A171E | Missense Mutation (SNP) | VAF 22/115 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.048); catalogued as rs766090858, COSV70444863, COSV70445145; called by muse, mutect2, varscan2
- DIP2C | c.2554G>A p.E852K | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV55148506; called by muse, mutect2, varscan2
- DISP3 | c.1415G>A p.C472Y | Missense Mutation (SNP) | VAF 22/269 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1263650241, COSV53821782; called by muse, mutect2
- DISP3 | c.3376-1G>T p.X1126_splice | Splice Site (SNP) | VAF 30/128 reads (23%) | catalogued as COSV53821800; called by muse, mutect2, varscan2
- DLL3 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 76/252 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.38); catalogued as COSV52693610; called by muse, mutect2, varscan2
- DNAH9 | c.4908G>A p.M1636I | Missense Mutation (SNP) | VAF 6/139 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as rs1314346085, COSV52337565; called by muse, mutect2
- DNAH9 | c.9245A>T p.Q3082L | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52337591; called by muse, varscan2
- DNER | c.1246T>C p.C416R | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59161139; called by muse, mutect2
- DSCAM | c.770G>A p.R257H | Missense Mutation (SNP) | VAF 17/120 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.434); catalogued as rs373921750; called by muse, mutect2, varscan2
- DSCAML1 | c.1894G>T p.E632* (on ENST00000321322; = p.E572* on NM_020693.4) | Nonsense Mutation (SNP) | VAF 61/149 reads (41%) | catalogued as COSV58383444; called by muse, mutect2, varscan2
- DSG3 | c.1457C>A p.P486H | Missense Mutation (SNP) | VAF 26/306 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); catalogued as COSV57124603; called by muse, mutect2
- DUOX1 | c.3085C>A p.Q1029K | Missense Mutation (SNP) | VAF 32/117 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.14); catalogued as COSV58477926; called by muse, mutect2, varscan2
- DUSP22 | c.271G>T p.G91W | Missense Mutation (SNP) | VAF 26/356 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60524272; called by muse, mutect2
- DYNC1H1 | c.6397G>T p.E2133* | Nonsense Mutation (SNP) | VAF 27/87 reads (31%) | catalogued as COSV64134814; called by muse, mutect2, varscan2
- DYRK4 | c.1337A>G p.K446R | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV50537998; called by muse, mutect2, varscan2
- EBF2 | c.996G>C p.R332S | Missense Mutation (SNP) | VAF 23/148 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.925); catalogued as COSV68776392, COSV68779949; called by muse, mutect2, varscan2
- EDA2R | c.264C>T p.P88= | Splice Region (SNP) | VAF 11/30 reads (37%) | catalogued as COSV53630426; called by muse, mutect2, varscan2
- EDIL3 | c.1398G>C p.R466S | Missense Mutation (SNP) | VAF 46/187 reads (25%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.918); catalogued as COSV56882919; called by muse, mutect2, varscan2
- EDN3 | c.251C>A p.A84E | Missense Mutation (SNP) | VAF 17/161 reads (11%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as rs142051051, COSV61107321; called by muse, mutect2, varscan2
- EHD3 | c.666C>A p.D222E | Missense Mutation (SNP) | VAF 8/120 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV59029442; called by muse, mutect2
- EIF4A2 | c.976G>T p.V326F | Missense Mutation (SNP) | VAF 95/323 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.75); catalogued as COSV56215789; called by muse, mutect2, varscan2
- ELF1 | c.1537C>G p.Q513E | Missense Mutation (SNP) | VAF 12/150 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.137); catalogued as COSV53497380; called by muse, mutect2
- ELF2 | c.1292C>G p.P431R (on ENST00000379550 / NM_001331036.2; = p.P371R on NM_006874.4) | Missense Mutation (SNP) | VAF 9/222 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.847); catalogued as COSV55491892; called by muse, mutect2
- ELF2 | c.599C>G p.P200R (on ENST00000379550 / NM_001331036.2; = p.P140R on NM_006874.4) | Missense Mutation (SNP) | VAF 34/269 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV55491915; called by muse, mutect2, varscan2
- EMILIN2 | c.1090G>T p.G364* | Nonsense Mutation (SNP) | VAF 36/166 reads (22%) | catalogued as COSV54421597; called by muse, mutect2, varscan2
- ENAH | c.1432G>T p.E478* | Nonsense Mutation (SNP) | VAF 13/46 reads (28%) | catalogued as COSV52865586, COSV52868416; called by muse, mutect2, varscan2
- EPHA5 | c.2188C>A p.Q730K | Missense Mutation (SNP) | VAF 63/338 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV56633773; called by muse, mutect2, varscan2
- EPHA6 | c.711C>A p.N237K | Missense Mutation (SNP) | VAF 102/479 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.068); catalogued as COSV67561544; called by muse, mutect2, varscan2
- EPHA7 | c.2500G>A p.E834K | Missense Mutation (SNP) | VAF 33/110 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65178175; called by muse, mutect2, varscan2
- EPX | c.171-2A>T p.X57_splice | Splice Site (SNP) | VAF 80/438 reads (18%) | catalogued as COSV56595278; called by muse, mutect2, varscan2
- EPYC | c.899C>A p.P300H | Missense Mutation (SNP) | VAF 72/168 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53798686, COSV53800095; called by muse, mutect2, varscan2
- ERG | c.443A>C p.Q148P | Missense Mutation (SNP) | VAF 22/133 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV55727958; called by muse, mutect2, varscan2
- ERICH3 | c.604-1G>C p.X202_splice | Splice Site (SNP) | VAF 18/224 reads (8%) | catalogued as COSV58600961; called by muse, mutect2
- ETNPPL | c.841G>A p.G281S | Missense Mutation (SNP) | VAF 64/262 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56594815, COSV56595625; called by muse, mutect2, varscan2
- EXOC5 | c.1600A>C p.T534P | Missense Mutation (SNP) | VAF 14/103 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.583); catalogued as COSV61770256; called by muse, mutect2, varscan2
- EXT2 | c.1654G>T p.G552C (on ENST00000343631; = p.G585C on NM_000401.3) | Missense Mutation (SNP) | VAF 45/251 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100640528, COSV59146368; called by muse, mutect2, varscan2
- EXT2 | c.1655G>T p.G552V (on ENST00000343631; = p.G585V on NM_000401.3) | Missense Mutation (SNP) | VAF 45/250 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100640529; called by muse, mutect2, varscan2
- F13A1 | c.29G>A p.G10E | Missense Mutation (SNP) | VAF 101/463 reads (22%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.043); catalogued as COSV53554408; called by muse, mutect2, varscan2
- F8 | c.4996C>T p.Q1666* | Nonsense Mutation (SNP) | VAF 10/140 reads (7%) | catalogued as COSV64270193; called by muse, mutect2
- FAM120A | c.2287G>T p.D763Y | Missense Mutation (SNP) | VAF 18/288 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV52901843, COSV99464656; called by muse, mutect2
- FAM171B | c.1189G>T p.V397F | Missense Mutation (SNP) | VAF 109/387 reads (28%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.767); catalogued as COSV59001183; called by muse, mutect2, varscan2
- FAM47C | c.484G>C p.A162P | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as COSV63724173, COSV63727538; called by muse, mutect2, varscan2
- FAM47C | c.1031C>T p.P344L | Missense Mutation (SNP) | VAF 67/169 reads (40%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.519); catalogued as rs1251517581, COSV63724190; called by muse, mutect2, varscan2
- FAM83C | c.603C>A p.Y201* | Nonsense Mutation (SNP) | VAF 65/205 reads (32%) | catalogued as COSV65582262, COSV65584138; called by muse, mutect2, varscan2
- FBLIM1 | c.577C>T p.R193* | Nonsense Mutation (SNP) | VAF 12/180 reads (7%) | catalogued as rs140794901; called by muse, mutect2
- FCRL4 | c.917T>A p.L306Q | Missense Mutation (SNP) | VAF 69/249 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54860250; called by muse, mutect2, varscan2
- FCRLA | c.296C>A p.S99Y (on ENST00000367959; = p.S76Y on NM_032738.4) | Missense Mutation (SNP) | VAF 36/225 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV99375736; called by muse, varscan2
- FER1L6 | c.4814C>A p.T1605N | Missense Mutation (SNP) | VAF 74/180 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); catalogued as COSV67548408; called by muse, mutect2, varscan2
- FGB | c.1046G>A p.G349E | Missense Mutation (SNP) | VAF 20/218 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.929); catalogued as COSV57417632; called by muse, mutect2
- FHDC1 | c.1186G>A p.E396K | Missense Mutation (SNP) | VAF 64/281 reads (23%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.796); catalogued as COSV52598100; called by muse, mutect2, varscan2
- FHL1 | c.32G>T p.R11M | Missense Mutation (SNP) | VAF 114/300 reads (38%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.957); catalogued as COSV61779961; called by muse, mutect2, varscan2
- FHL5 | c.757G>T p.G253W | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.1); catalogued as COSV58735599; called by muse, mutect2, varscan2
- FLG | c.1882C>G p.Q628E | Missense Mutation (SNP) | VAF 259/853 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.124); catalogued as rs779204654, COSV64237807; called by muse, mutect2, varscan2
- FRAS1 | c.5948T>A p.L1983Q | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV53593821; called by muse, mutect2
- FREM1 | c.4389G>T p.Q1463H | Missense Mutation (SNP) | VAF 46/136 reads (34%) | SIFT tolerated (0.35); PolyPhen benign (0.007); catalogued as COSV66518765; called by muse, mutect2, varscan2
- FRMPD2 | c.922-2A>T p.X308_splice | Splice Site (SNP) | VAF 8/98 reads (8%) | catalogued as COSV59715779; called by muse, mutect2
- FRY | c.5921A>T p.E1974V | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.074); catalogued as COSV66566181; called by muse, mutect2, varscan2
- FSIP2 | c.18260C>A p.S6087Y | Missense Mutation (SNP) | VAF 52/187 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100554334; called by muse, mutect2, varscan2
- FUT8 | c.611G>C p.C204S (on ENST00000360689 / NM_001371534.1; = p.C41S on NM_004480.4) | Missense Mutation (SNP) | VAF 35/98 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61280796; called by muse, mutect2, varscan2
- FYCO1 | c.259G>T p.G87W | Missense Mutation (SNP) | VAF 82/246 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56114071; called by muse, mutect2, varscan2
- G2E3 | c.1378G>T p.G460C | Missense Mutation (SNP) | VAF 19/135 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52838833; called by mutect2, varscan2
- GAK | c.329A>T p.E110V | Missense Mutation (SNP) | VAF 22/267 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); catalogued as COSV58503188; called by muse, mutect2
- GALC | c.1757G>T p.G586V | Missense Mutation (SNP) | VAF 46/430 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV54323602; called by muse, mutect2, varscan2
- GANAB | c.1050G>T p.Q350H | Missense Mutation (SNP) | VAF 223/924 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.017); catalogued as COSV60462469; called by muse, mutect2, varscan2
- GARNL3 | c.230C>G p.A77G | Missense Mutation (SNP) | VAF 17/196 reads (9%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV59224143; called by muse, mutect2
- GAS2 | c.191G>T p.G64V | Missense Mutation (SNP) | VAF 56/229 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53404911; called by muse, mutect2, varscan2
- GDNF | c.459G>T p.E153D | Missense Mutation (SNP) | VAF 57/336 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.125); catalogued as COSV58478486; called by muse, mutect2, varscan2
- GJB1 | c.123G>T p.E41D | Missense Mutation (SNP) | VAF 38/82 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as CM066092, COSV62139558; called by muse, mutect2, varscan2
- GLDC | c.2851T>C p.S951P | Missense Mutation (SNP) | VAF 6/73 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV58677039; called by muse, mutect2
- GLRX3 | c.276+1G>T p.X92_splice | Splice Site (SNP) | VAF 63/174 reads (36%) | catalogued as COSV58691719; called by muse, mutect2, varscan2
- GMEB1 | c.1583C>T p.P528L | Missense Mutation (SNP) | VAF 19/150 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs148243859; called by muse, varscan2
- GNAQ | c.191G>T p.G64V | Missense Mutation (SNP) | VAF 47/248 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54108142; called by muse, mutect2, varscan2
- GPC5 | c.249G>T p.Q83H | Missense Mutation (SNP) | VAF 19/154 reads (12%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.95); catalogued as COSV65581502, COSV65582941; called by muse, mutect2, varscan2
- GPR139 | c.464C>A p.T155N | Missense Mutation (SNP) | VAF 40/203 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.295); catalogued as COSV58501876; called by muse, mutect2, varscan2
- GPR141 | c.655C>A p.Q219K | Missense Mutation (SNP) | VAF 68/363 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); catalogued as COSV57731470; called by muse, mutect2, varscan2
- GPR63 | c.700A>C p.T234P | Missense Mutation (SNP) | VAF 71/216 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.031); catalogued as rs866908729, COSV57739865; called by muse, mutect2, varscan2
- GPR63 | c.16G>T p.V6L | Missense Mutation (SNP) | VAF 33/145 reads (23%) | SIFT tolerated, low confidence (0.95); PolyPhen benign (0); catalogued as rs1168525347, COSV57739874; called by muse, mutect2, varscan2
- GRID1 | c.919G>T p.D307Y | Missense Mutation (SNP) | VAF 80/190 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV60016391, COSV60052524; called by muse, mutect2, varscan2
- GRIN2D | c.2480T>A p.I827N | Missense Mutation (SNP) | VAF 67/249 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53517920; called by muse, mutect2, varscan2
- GRK2 | c.990C>G p.H330Q | Missense Mutation (SNP) | VAF 27/416 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57950625, COSV57951172; called by muse, mutect2
- GRK5 | c.1453A>T p.T485S | Missense Mutation (SNP) | VAF 7/109 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.088); catalogued as COSV64865769; called by muse, mutect2
- GRM8 | c.2096C>A p.T699N | Missense Mutation (SNP) | VAF 37/107 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.873); catalogued as COSV58807197; called by muse, mutect2, varscan2
- GSTZ1 | c.17C>T p.P6L | Missense Mutation (SNP) | VAF 10/160 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.865); catalogued as rs939750689, COSV53622919; called by muse, mutect2
- GTF3C1 | c.881A>T p.Y294F | Missense Mutation (SNP) | VAF 20/440 reads (5%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.864); catalogued as COSV62239353; called by muse, mutect2
- GTPBP3 | c.115C>G p.L39V | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.951); catalogued as rs746303532, COSV50173654; called by muse, mutect2, varscan2
- HAS2 | c.448A>T p.N150Y | Missense Mutation (SNP) | VAF 52/868 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.078); catalogued as COSV58262359; called by muse, mutect2
- HDAC2 | c.769G>A p.A257T | Missense Mutation (SNP) | VAF 50/184 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); catalogued as COSV64037464; called by muse, mutect2, varscan2
- HDAC4 | c.850C>T p.P284S | Missense Mutation (SNP) | VAF 49/171 reads (29%) | SIFT tolerated (0.33); PolyPhen benign (0.015); catalogued as COSV61860646; called by muse, mutect2, varscan2
- HEATR5A | c.4460C>A p.A1487E | Missense Mutation (SNP) | VAF 63/214 reads (29%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.811); catalogued as rs757014948, COSV66338870; called by muse, mutect2, varscan2
- HECW1 | c.14T>A p.L5Q | Missense Mutation (SNP) | VAF 59/221 reads (27%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.995); catalogued as COSV67823496; called by muse, mutect2, varscan2
- HEMGN | c.335G>T p.G112V | Missense Mutation (SNP) | VAF 16/177 reads (9%) | SIFT tolerated (0.5); PolyPhen benign (0.028); catalogued as COSV52325428; called by muse, mutect2
- HEPH | c.1557G>T p.W519C (on ENST00000343002; = p.W252C on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57960018; called by muse, mutect2, varscan2
- HES2 | c.236C>T p.A79V | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.036); catalogued as COSV64732231; called by muse, mutect2, varscan2
- HHATL | c.1011G>T p.T337= | Splice Region (SNP) | VAF 13/54 reads (24%) | catalogued as COSV55133017; called by muse, mutect2, varscan2
- HMCN1 | c.1247A>G p.Q416R | Missense Mutation (SNP) | VAF 64/246 reads (26%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.986); catalogued as COSV54881632; called by muse, mutect2, varscan2
- HNF4G | c.1104C>A p.I368= (on ENST00000354370 / NM_001330561.2; = p.I415= on NM_004133.5) | Splice Region (SNP) | VAF 21/181 reads (12%) | catalogued as COSV62966208; called by muse, mutect2, varscan2
- HNRNPD | c.777del p.K260Rfs*109 (on ENST00000313899 / NM_031370.3; = p.K260Rfs*60 on NM_002138.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 146/658 reads (22%) | catalogued as COSV100002762; called by mutect2, varscan2
- HOXA1 | c.205C>A p.H69N | Missense Mutation (SNP) | VAF 29/106 reads (27%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.466); catalogued as COSV56065371; called by muse, mutect2, varscan2
- HOXA2 | c.850C>A p.L284M | Missense Mutation (SNP) | VAF 84/286 reads (29%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.62); catalogued as rs1278253439, COSV56065380; called by muse, mutect2, varscan2
- HOXA7 | c.136G>C p.A46P | Missense Mutation (SNP) | VAF 24/151 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.022); catalogued as COSV54216847, COSV99636727; called by muse, mutect2, varscan2
- HP1BP3 | c.1205G>T p.G402V | Missense Mutation (SNP) | VAF 15/160 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100391598; called by muse, mutect2
- HSPH1 | c.2125G>A p.A709T | Missense Mutation (SNP) | VAF 23/179 reads (13%) | SIFT tolerated (0.39); PolyPhen benign (0.313); catalogued as COSV60710458; called by muse, mutect2, varscan2
- IFNA2 | c.374G>T p.G125V | Missense Mutation (SNP) | VAF 41/375 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0.359); catalogued as COSV66505368, COSV66505777; called by muse, mutect2, varscan2
- IGFBPL1 | c.506G>T p.G169V | Missense Mutation (SNP) | VAF 29/206 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1186519875, COSV66617825; called by muse, mutect2, varscan2
- IGKV3-15 | c.208G>T p.G70C | Missense Mutation (SNP) | VAF 26/276 reads (9%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.656); catalogued as rs553971399; called by muse, mutect2
- IGLON5 | c.469G>T p.V157L | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated (0.27); PolyPhen benign (0.14); catalogued as rs201159850, COSV54534813; called by muse, mutect2, varscan2
- IGSF10 | c.7490C>A p.T2497K | Missense Mutation (SNP) | VAF 106/314 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as COSV56370576; called by muse, mutect2, varscan2
- IGSF10 | c.3142G>T p.E1048* | Nonsense Mutation (SNP) | VAF 85/246 reads (35%) | catalogued as COSV56782276, COSV56792468; called by muse, mutect2, varscan2
- IGSF5 | c.166G>T p.A56S | Missense Mutation (SNP) | VAF 23/136 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV66029450; called by muse, mutect2, varscan2
- IL25 | c.149A>G p.E50G | Missense Mutation (SNP) | VAF 16/137 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV59304981; called by muse, mutect2, varscan2
- ILF3 | c.1645G>C p.G549R | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.969); catalogued as COSV99139430; called by mutect2, varscan2
- INSL5 | c.66C>A p.S22R | Missense Mutation (SNP) | VAF 37/138 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as rs778970586, COSV58787976; called by muse, mutect2, varscan2
- INTS5 | c.1726C>T p.R576C | Missense Mutation (SNP) | VAF 13/160 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as rs201064662, COSV57950488; called by muse, mutect2
- INTU | c.2455G>T p.E819* | Nonsense Mutation (SNP) | VAF 44/173 reads (25%) | catalogued as COSV58869828; called by muse, mutect2, varscan2
- IPO8 | c.3020C>A p.A1007E | Missense Mutation (SNP) | VAF 48/137 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.044); catalogued as COSV56239193, COSV56239949; called by muse, mutect2, varscan2
- IPO8 | c.323+1G>T p.X108_splice | Splice Site (SNP) | VAF 46/182 reads (25%) | catalogued as COSV56239957, COSV56244872; called by muse, mutect2, varscan2
- IQGAP2 | c.98G>T p.R33L | Missense Mutation (SNP) | VAF 36/248 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.017); catalogued as rs369302838, COSV57168962; called by muse, mutect2, varscan2
- ISLR | c.509C>T p.T170I | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT tolerated (0.37); PolyPhen benign (0.007); catalogued as rs780036106, COSV51433111; called by muse, mutect2, varscan2
- ISOC1 | c.494G>A p.G165E | Missense Mutation (SNP) | VAF 33/129 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1240441068, COSV51491188; called by muse, mutect2, varscan2
- ITGA2B | c.2077G>T p.A693S | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.802); catalogued as COSV52231435; called by muse, mutect2, varscan2
- ITIH2 | c.803C>T p.A268V | Missense Mutation (SNP) | VAF 35/276 reads (13%) | SIFT tolerated (0.47); PolyPhen benign (0.154); catalogued as rs141514196; called by muse, mutect2, varscan2
- JMY | c.2528G>T p.R843I | Missense Mutation (SNP) | VAF 32/124 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.26); catalogued as COSV68659603; called by muse, mutect2, varscan2
- JRK | c.1411G>C p.A471P | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated (0.29); PolyPhen benign (0.03); catalogued as COSV70629562; called by muse, mutect2, varscan2
- KATNAL1 | c.1090A>G p.I364V | Missense Mutation (SNP) | VAF 20/127 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV66062713; called by muse, mutect2, varscan2
- KCNA4 | c.1896G>T p.K632N | Missense Mutation (SNP) | VAF 44/177 reads (25%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.001); catalogued as COSV60250931; called by muse, mutect2, varscan2
- KCNH1 | c.514G>T p.V172L | Missense Mutation (SNP) | VAF 97/282 reads (34%) | SIFT tolerated (0.68); PolyPhen benign (0.001); catalogued as COSV55071630; called by muse, mutect2, varscan2
- KCNJ12 | c.277G>T p.A93S | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.45); catalogued as COSV59164166; called by muse, varscan2
- KCNK6 | c.484G>T p.G162C | Missense Mutation (SNP) | VAF 14/112 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54579015; called by muse, mutect2, varscan2
- KDM3A | c.3685C>T p.Q1229* | Nonsense Mutation (SNP) | VAF 37/280 reads (13%) | catalogued as COSV57218054, COSV57218797; called by muse, mutect2, varscan2
- KIAA0319 | c.710C>G p.P237R | Missense Mutation (SNP) | VAF 9/200 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.296); catalogued as COSV65496762; called by muse, mutect2
- KIAA0895 | c.472G>T p.V158L (on ENST00000297063 / NM_001100425.2; = p.V107L on NM_015314.3) | Missense Mutation (SNP) | VAF 68/240 reads (28%) | SIFT tolerated, low confidence (0.81); PolyPhen benign (0); catalogued as COSV51709169; called by muse, mutect2, varscan2
- KIAA1109 | c.12352G>T p.G4118C | Missense Mutation (SNP) | VAF 30/143 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.766); catalogued as COSV52664312; called by muse, mutect2, varscan2
- KIAA1549L | c.1835C>A p.T612N (on ENST00000321505; = p.T909N on NM_012194.3) | Missense Mutation (SNP) | VAF 15/221 reads (7%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.052); catalogued as COSV55770406; called by muse, mutect2
- KIF27 | c.1794A>T p.R598S | Missense Mutation (SNP) | VAF 24/309 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.078); catalogued as COSV52825754; called by muse, mutect2
- KLHL1 | c.1753A>T p.S585C | Missense Mutation (SNP) | VAF 13/102 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV64767887; called by muse, mutect2, varscan2
- KLHL20 | c.1293G>T p.E431D | Missense Mutation (SNP) | VAF 126/435 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV52940557; called by muse, mutect2, varscan2
- KLHL6 | c.1661C>G p.A554G | Missense Mutation (SNP) | VAF 29/120 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.46); catalogued as COSV100384738, COSV58064813; called by muse, mutect2, varscan2
- KLK4 | c.285G>T p.Q95H | Missense Mutation (SNP) | VAF 42/137 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV60675824, COSV60677017; called by muse, mutect2, varscan2
- KRT37 | c.869A>C p.D290A | Missense Mutation (SNP) | VAF 12/382 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV56657076; called by muse, mutect2
- KRT6A | c.584G>T p.W195L | Missense Mutation (SNP) | VAF 59/159 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.734); catalogued as COSV58104048; called by muse, mutect2, varscan2
- KRTAP10-8 | c.547G>T p.A183S | Missense Mutation (SNP) | VAF 110/416 reads (26%) | SIFT tolerated (0.31); PolyPhen benign (0.012); catalogued as COSV58166017, COSV58166627; called by muse, mutect2, varscan2
- KRTAP13-1 | c.304T>G p.F102V | Missense Mutation (SNP) | VAF 6/120 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.069); catalogued as COSV62662950; called by muse, mutect2
- LAMC1 | c.2042G>T p.G681V | Missense Mutation (SNP) | VAF 27/131 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV51133675; called by muse, mutect2, varscan2
- LAMC3 | c.1023G>T p.E341D | Missense Mutation (SNP) | VAF 20/205 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); catalogued as COSV63088959; called by muse, mutect2, varscan2
- LBP | c.911C>A p.T304K | Missense Mutation (SNP) | VAF 68/233 reads (29%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.627); catalogued as COSV54138968; called by muse, varscan2
- LELP1 | c.185C>A p.P62H | Missense Mutation (SNP) | VAF 27/198 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as COSV64202309; called by muse, mutect2, varscan2
- LETMD1 | c.206G>T p.G69V | Missense Mutation (SNP) | VAF 76/173 reads (44%) | SIFT tolerated (0.17); PolyPhen benign (0.143); catalogued as COSV50396781; called by muse, mutect2, varscan2
- LGALS9 | c.191C>T p.P64L | Missense Mutation (SNP) | VAF 75/236 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.961); catalogued as COSV56348141; called by muse, mutect2, varscan2
- LGI3 | c.1519G>T p.E507* | Nonsense Mutation (SNP) | VAF 15/77 reads (19%) | catalogued as COSV60443023; called by muse, mutect2, varscan2
- LHCGR | c.583A>C p.N195H | Missense Mutation (SNP) | VAF 4/74 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54293448; called by muse, mutect2
- LILRB1 | c.1631C>A p.S544* (on ENST00000427581; = p.S494* on NM_006669.6) | Nonsense Mutation (SNP) | VAF 66/240 reads (28%) | catalogued as COSV61116402; called by muse, varscan2
- LIPK | c.111G>C p.Q37H | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV68200711; called by muse, mutect2, varscan2
- LONRF3 | c.1948G>T p.D650Y (on ENST00000371628 / NM_001031855.3; = p.D609Y on NM_024778.5) | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100504266, COSV59150402; called by muse, mutect2, varscan2
- LOXL4 | c.1172C>A p.P391H | Missense Mutation (SNP) | VAF 100/292 reads (34%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as COSV53255527; called by muse, mutect2, varscan2
- LPA | c.4865A>T p.Q1622L | Missense Mutation (SNP) | VAF 67/214 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.053); catalogued as COSV60297972; called by muse, mutect2, varscan2
- LRAT | c.655G>T p.A219S | Missense Mutation (SNP) | VAF 101/495 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.013); catalogued as COSV60476607; called by muse, mutect2, varscan2
- LRIT2 | c.1241G>T p.G414V | Missense Mutation (SNP) | VAF 97/251 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60565398; called by muse, mutect2, varscan2
- LRIT2 | c.1240G>T p.G414* | Nonsense Mutation (SNP) | VAF 97/248 reads (39%) | catalogued as rs199824710, COSV100258534, COSV60564499; called by muse, mutect2, varscan2
- LRPPRC | c.3015G>C p.Q1005H | Missense Mutation (SNP) | VAF 46/173 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV53234833; called by muse, mutect2, varscan2
- LRRC66 | c.2643A>C p.*881Yext*24 | Nonstop Mutation (SNP) | VAF 9/130 reads (7%) | catalogued as COSV58632340; called by muse, mutect2
- LRRC7 | c.3304A>G p.K1102E (on ENST00000651989 / NM_001370785.2; = p.K1069E on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 30/92 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV50417079; called by muse, mutect2, varscan2
- LTBP1 | c.1102G>T p.G368C (on ENST00000404816 / NM_206943.4; = p.G42C on NM_000627.4) | Missense Mutation (SNP) | VAF 25/125 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63181350, COSV63190597; called by muse, mutect2, varscan2
- LTBP3 | c.1775C>T p.P592L | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.46); catalogued as rs1400831758, COSV57238921; called by muse, mutect2, varscan2
- LYST | c.430A>G p.R144G | Missense Mutation (SNP) | VAF 23/318 reads (7%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.012); catalogued as COSV67703998; called by muse, mutect2
- LZTR1 | c.1398del p.S467Afs*89 | Frame Shift Del (DEL) | VAF 8/24 reads (33%) | catalogued as CM140928, COSV53145166; called by mutect2, pindel
- LZTS2 | c.1031G>T p.R344L | Missense Mutation (SNP) | VAF 47/141 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV64650995; called by muse, mutect2, varscan2
- MAGEC1 | c.2095C>A p.L699I | Missense Mutation (SNP) | VAF 80/158 reads (51%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.063); catalogued as COSV53569035; called by muse, mutect2, varscan2
- MAST4 | c.7411G>A p.G2471R (on ENST00000403625 / NM_001164664.2; = p.G2282R on NM_015183.3) | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.007); catalogued as rs1379777873, COSV55117583; called by muse, mutect2
- MCPH1 | c.2107C>T p.R703C | Missense Mutation (SNP) | VAF 26/120 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761698331, COSV60910693; called by muse, mutect2, varscan2
- MEF2C | c.373G>T p.D125Y | Missense Mutation (SNP) | VAF 50/244 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100425521, COSV60926486; called by muse, mutect2, varscan2
- MEP1A | c.2179G>T p.A727S | Missense Mutation (SNP) | VAF 72/343 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.334); catalogued as COSV57918341; called by muse, mutect2, varscan2
- METTL4 | c.268C>T p.P90S | Missense Mutation (SNP) | VAF 23/149 reads (15%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV55247144; called by muse, mutect2, varscan2
- MGAM | c.3422C>A p.S1141Y | Missense Mutation (SNP) | VAF 88/288 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.393); catalogued as COSV72073861; called by muse, mutect2, varscan2
- MICAL3 | c.3970G>T p.V1324L | Missense Mutation (SNP) | VAF 71/174 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.079); catalogued as COSV71588069; called by muse, mutect2, varscan2
- MLYCD | c.298G>T p.G100C | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.263); catalogued as COSV52304185; called by muse, mutect2, varscan2
- MMP10 | c.1088G>T p.R363I | Missense Mutation (SNP) | VAF 16/312 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV54245588; called by muse, mutect2
- MMP9 | c.62C>T p.P21L | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.997); catalogued as COSV64884321; called by muse, mutect2, varscan2
- MNDA | c.742C>A p.H248N | Missense Mutation (SNP) | VAF 30/140 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.4); catalogued as COSV63740075; called by muse, mutect2, varscan2
- MRC2 | c.1838A>G p.Y613C | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.601); catalogued as COSV100315906; called by muse, mutect2
- MRGPRX3 | c.548G>A p.W183* | Nonsense Mutation (SNP) | VAF 28/180 reads (16%) | catalogued as COSV66933290; called by muse, mutect2, varscan2
- MRPL30 | c.65G>T p.G22V | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.34); PolyPhen benign (0.299); catalogued as rs773756100, COSV57666628; called by muse, mutect2, varscan2
- MSLN | c.705-2A>T p.X235_splice | Splice Site (SNP) | VAF 18/59 reads (31%) | catalogued as COSV53499669; called by muse, mutect2, varscan2
- MUC16 | c.33710C>A p.S11237* | Nonsense Mutation (SNP) | VAF 14/40 reads (35%) | catalogued as COSV67449711; called by muse, mutect2, varscan2
- MUC2 | c.433C>A p.L145I | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.094); catalogued as rs1488053760; called by muse, mutect2, varscan2
- MUC21 | c.953C>A p.S318Y | Missense Mutation (SNP) | VAF 56/371 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.5); catalogued as rs748992183, COSV100888839; called by muse, varscan2
- MUC21 | c.1223C>A p.S408Y | Missense Mutation (SNP) | VAF 46/347 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.865); catalogued as COSV66220347; called by muse, varscan2
- MUSK | c.2500C>A p.L834I | Missense Mutation (SNP) | VAF 25/91 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51878545; called by muse, mutect2, varscan2
- MX2 | c.1408C>T p.Q470* | Nonsense Mutation (SNP) | VAF 21/150 reads (14%) | catalogued as rs751048457, COSV58095396; called by muse, mutect2, varscan2
- MXRA5 | c.2410T>G p.L804V | Missense Mutation (SNP) | VAF 16/204 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54226312; called by muse, mutect2
- MYB | c.1828C>A p.P610T | Missense Mutation (SNP) | VAF 67/243 reads (28%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV57196289; called by muse, mutect2, varscan2
- MYH1 | c.4809C>A p.S1603R | Missense Mutation (SNP) | VAF 136/415 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.02); catalogued as COSV56844561; called by muse, varscan2
- MYH14 | c.3362G>C p.G1121A | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as COSV51811558; called by muse, mutect2, varscan2
- MYO16 | c.4987C>A p.P1663T | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.007); catalogued as COSV100696154, COSV62745178; called by muse, mutect2, varscan2
- MYO1D | c.394G>T p.E132* | Nonsense Mutation (SNP) | VAF 40/175 reads (23%) | catalogued as COSV59008301; called by muse, mutect2, varscan2
- MYO1G | c.628G>C p.G210R | Missense Mutation (SNP) | VAF 42/218 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.823); catalogued as COSV51853360; called by muse, mutect2, varscan2
- MYOM3 | c.830T>A p.L277Q | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV58390639; called by muse, mutect2, varscan2
- NAGPA | c.1058G>T p.R353L | Missense Mutation (SNP) | VAF 18/77 reads (23%) | PolyPhen benign (0.097); catalogued as COSV56569394; called by muse, mutect2, varscan2
- NBAS | c.5139-1G>T p.X1713_splice | Splice Site (SNP) | VAF 25/84 reads (30%) | catalogued as COSV55714223; called by muse, mutect2, varscan2
- NBAS | c.4349G>T p.G1450V | Missense Mutation (SNP) | VAF 35/266 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV55714234; called by muse, mutect2, varscan2
- NCAN | c.1292C>A p.P431H | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.436); catalogued as COSV99386721; called by muse, mutect2
- NCAPH | c.455A>G p.K152R | Missense Mutation (SNP) | VAF 6/83 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV53635256; called by muse, mutect2
- NDST4 | c.1814C>G p.T605R | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52110805; called by muse, mutect2, varscan2
- NEDD4 | c.2735A>G p.N912S (on ENST00000508342 / NM_001284338.1; = p.N493S on NM_006154.4) | Missense Mutation (SNP) | VAF 43/105 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.758); catalogued as COSV59059163; called by muse, mutect2, varscan2
- NHSL2 | c.1930G>T p.V644L (on ENST00000510661; = p.V1010L on NM_001013627.2) | Missense Mutation (SNP) | VAF 25/51 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.03); catalogued as COSV65452562; called by muse, mutect2, varscan2
- NID1 | c.1379C>A p.S460Y | Missense Mutation (SNP) | VAF 38/155 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51615832; called by muse, mutect2, varscan2
- NID1 | c.1250G>T p.G417V | Missense Mutation (SNP) | VAF 61/261 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); catalogued as COSV51615849; called by muse, mutect2, varscan2
- NIPAL3 | c.802G>T p.D268Y | Missense Mutation (SNP) | VAF 43/172 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV50230305; called by muse, mutect2, varscan2
- NLRP14 | c.3251A>T p.E1084V | Missense Mutation (SNP) | VAF 8/158 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.22); catalogued as COSV55064700; called by muse, mutect2
- NLRP2 | c.2290G>T p.G764C | Missense Mutation (SNP) | VAF 43/131 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54752874; called by muse, mutect2, varscan2
- NLRP3 | c.1051G>T p.V351L | Missense Mutation (SNP) | VAF 71/275 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.029); catalogued as CM060243, CM071606, COSV60220950; called by muse, mutect2, varscan2
- NLRP4 | c.617C>A p.S206Y | Missense Mutation (SNP) | VAF 65/226 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV100015586, COSV56709094; called by muse, mutect2, varscan2
- NLRP4 | c.1267G>T p.G423W | Missense Mutation (SNP) | VAF 52/176 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56709107, COSV56714256; called by mutect2, varscan2
- NMRK2 | c.376G>T p.E126* | Nonsense Mutation (SNP) | VAF 14/53 reads (26%) | catalogued as COSV51454954, COSV99396383; called by muse, mutect2, varscan2
- NMUR1 | c.629G>A p.R210Q | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.647); catalogued as rs775345754, COSV59403614; called by muse, mutect2, varscan2
- NNMT | c.457C>T p.P153S | Missense Mutation (SNP) | VAF 12/277 reads (4%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as COSV55473008; called by muse, mutect2
- NNMT | c.650G>T p.G217V | Missense Mutation (SNP) | VAF 14/182 reads (8%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.79); catalogued as COSV55473096; called by muse, mutect2
- NOS1AP | c.1191G>T p.E397D | Missense Mutation (SNP) | VAF 78/419 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV62632536; called by muse, mutect2, varscan2
- NOTCH4 | c.4183G>T p.D1395Y | Missense Mutation (SNP) | VAF 31/93 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); catalogued as COSV66679167, COSV66679207; called by muse, mutect2, varscan2
- NPY2R | c.871G>T p.V291F | Missense Mutation (SNP) | VAF 25/105 reads (24%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.47); catalogued as COSV61527392; called by muse, mutect2, varscan2
- NRSN1 | c.166A>T p.R56W | Missense Mutation (SNP) | VAF 22/122 reads (18%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.924); catalogued as COSV65893720; called by muse, mutect2, varscan2
- NTAQ1 | c.392G>T p.R131I | Missense Mutation (SNP) | VAF 26/176 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54873826, COSV54876634; called by muse, mutect2, varscan2
- NUF2 | c.276-1G>T p.X92_splice | Splice Site (SNP) | VAF 20/172 reads (12%) | catalogued as COSV54842363; called by muse, mutect2, varscan2
- NUGGC | c.1886A>G p.K629R | Missense Mutation (SNP) | VAF 39/227 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.01); catalogued as COSV58432892; called by muse, mutect2, varscan2
- NUGGC | c.241G>A p.G81R | Missense Mutation (SNP) | VAF 22/127 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.66); catalogued as COSV58432905; called by muse, mutect2, varscan2
- NUP58 | c.121G>T p.G41W | Missense Mutation (SNP) | VAF 24/161 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67750980; called by muse, mutect2, varscan2
- OBSCN | c.16484C>A p.S5495* | Nonsense Mutation (SNP) | VAF 51/237 reads (22%) | catalogued as COSV52747622; called by muse, mutect2, varscan2
- OGN | c.70C>A p.Q24K | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV99363999; called by muse, mutect2, varscan2
- OR13C4 | c.779C>A p.A260E | Missense Mutation (SNP) | VAF 14/180 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.442); catalogued as rs1231005102, COSV52926000; called by muse, mutect2
- OR13C4 | c.343del p.G116Afs*2 | Frame Shift Del (DEL) | VAF 24/249 reads (10%) | catalogued as COSV52926735; called by mutect2, pindel, varscan2
- OR14A16 | c.478G>T p.G160C | Missense Mutation (SNP) | VAF 60/308 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.434); catalogued as COSV62926213; called by muse, mutect2, varscan2
- OR1J4 | c.512A>T p.D171V | Missense Mutation (SNP) | VAF 17/148 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.183); catalogued as COSV61589602; called by muse, mutect2, varscan2
- OR1N2 | c.156C>G p.I52M | Missense Mutation (SNP) | VAF 24/254 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV65460303; called by muse, mutect2
- OR2B11 | c.822G>T p.Q274H | Missense Mutation (SNP) | VAF 96/480 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); catalogued as COSV59509455; called by muse, mutect2, varscan2
- OR2C3 | c.458G>T p.G153V | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV63574549; called by muse, mutect2
- OR2G2 | c.467T>C p.I156T | Missense Mutation (SNP) | VAF 148/555 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV60739619; called by muse, mutect2, varscan2
- OR2G3 | c.753C>A p.F251L | Missense Mutation (SNP) | VAF 26/128 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV60680996; called by muse, mutect2, varscan2
- OR2L3 | c.549G>A p.M183I | Missense Mutation (SNP) | VAF 65/384 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.17); catalogued as COSV63454631; called by muse, mutect2, varscan2
- OR2M7 | c.257T>A p.L86* | Nonsense Mutation (SNP) | VAF 206/751 reads (27%) | catalogued as COSV58738152; called by muse, mutect2
- OR2M7 | c.5C>A p.A2E | Missense Mutation (SNP) | VAF 86/431 reads (20%) | SIFT tolerated (0.64); PolyPhen benign (0.013); catalogued as COSV58738159; called by muse, mutect2, varscan2
- OR2T10 | c.122G>C p.W41S | Missense Mutation (SNP) | VAF 34/73 reads (47%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV100393641, COSV57896246; called by muse, mutect2, varscan2
- OR2T34 | c.614A>T p.Y205F | Missense Mutation (SNP) | VAF 80/500 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.173); catalogued as COSV60899780, COSV60900889; called by muse, mutect2, varscan2
- OR2T8 | c.97G>T p.V33F | Missense Mutation (SNP) | VAF 36/280 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs369963137, COSV60661777; called by muse, varscan2
- OR2W3 | c.423C>G p.C141W | Missense Mutation (SNP) | VAF 36/168 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64456220, COSV64456361, COSV64456545; called by muse, mutect2, varscan2
- OR2W3 | c.734T>A p.L245H | Missense Mutation (SNP) | VAF 20/329 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV64456227; called by muse, mutect2
- OR4A15 | c.215C>A p.S72Y | Missense Mutation (SNP) | VAF 92/335 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.172); catalogued as COSV59033850, COSV59034664; called by muse, mutect2, varscan2
- OR4B1 | c.571T>C p.F191L | Missense Mutation (SNP) | VAF 10/224 reads (4%) | SIFT tolerated (0.05); PolyPhen benign (0.297); catalogued as COSV58882160; called by muse, mutect2
- OR4D5 | c.333G>T p.K111N | Missense Mutation (SNP) | VAF 85/237 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.109); catalogued as COSV58305900; called by muse, mutect2, varscan2
- OR4D6 | c.206T>C p.L69P | Missense Mutation (SNP) | VAF 49/176 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.864); catalogued as COSV55659131; called by muse, mutect2, varscan2
- OR51Q1 | c.885T>A p.S295R | Missense Mutation (SNP) | VAF 16/127 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.02); catalogued as COSV56178029; called by muse, mutect2, varscan2
- OR52B4 | c.127G>T p.G43W | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68768633; called by muse, mutect2, varscan2
- OR52K1 | c.859C>G p.P287A | Missense Mutation (SNP) | VAF 69/325 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.307); catalogued as COSV56903092; called by muse, mutect2, varscan2
- OR5K3 | c.757C>A p.L253I | Missense Mutation (SNP) | VAF 40/239 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.158); catalogued as COSV67349767; called by muse, mutect2, varscan2
- OR6B2 | c.7G>C p.G3R | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV68791328; called by muse, mutect2, varscan2
- OR6C1 | c.127C>A p.L43I | Missense Mutation (SNP) | VAF 75/161 reads (47%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV101110430, COSV65572776; called by muse, mutect2, varscan2
- OR6K2 | c.190A>T p.S64C | Missense Mutation (SNP) | VAF 47/167 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.043); catalogued as COSV62743167; called by muse, mutect2, varscan2
- OR8J1 | c.550C>A p.L184M | Missense Mutation (SNP) | VAF 30/135 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV57316855; called by muse, mutect2, varscan2
- OSBPL6 | c.2605G>T p.A869S | Missense Mutation (SNP) | VAF 68/229 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as COSV51912195; called by muse, mutect2, varscan2
- OTOA | c.2058+1G>T p.X686_splice (on ENST00000286149; = p.X672_splice on NM_144672.4) | Splice Site (SNP) | VAF 35/201 reads (17%) | catalogued as COSV53750157; called by muse, mutect2, varscan2
- OTP | c.725C>A p.A242E | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.29); catalogued as COSV60568561; called by muse, mutect2
- OXSM | c.1069G>T p.A357S | Missense Mutation (SNP) | VAF 38/138 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.377); catalogued as COSV55000854, COSV99772001; called by muse, mutect2, varscan2
- PAK5 | c.204+1G>T p.X68_splice | Splice Site (SNP) | VAF 6/100 reads (6%) | catalogued as COSV100781169; called by muse, mutect2
- PALB2 | c.2956G>T p.D986Y | Missense Mutation (SNP) | VAF 61/317 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV55162891; called by muse, mutect2, varscan2
- PALD1 | c.871G>T p.E291* | Nonsense Mutation (SNP) | VAF 12/133 reads (9%) | catalogued as COSV54971230; called by muse, mutect2
- PAPPA2 | c.215C>G p.P72R | Missense Mutation (SNP) | VAF 112/551 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV62774202; called by muse, mutect2, varscan2
- PAQR9 | c.377C>A p.A126E | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.918); catalogued as COSV61417691, COSV61418890; called by muse, mutect2, varscan2
- PARP8 | c.1304G>A p.S435N | Missense Mutation (SNP) | VAF 53/228 reads (23%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0); catalogued as COSV55856668; called by muse, mutect2, varscan2
- PCDH10 | c.2843G>T p.G948V | Missense Mutation (SNP) | VAF 34/167 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV52088555; called by muse, mutect2, varscan2
- PCDH17 | c.2504G>C p.S835T | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT tolerated (0.58); PolyPhen benign (0.011); catalogued as COSV64972253; called by muse, mutect2, varscan2
- PCDHB7 | c.1402C>A p.L468M | Missense Mutation (SNP) | VAF 52/196 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.856); catalogued as COSV50755814, COSV50775321; called by muse, mutect2, varscan2
- PCDHGA8 | c.767C>A p.P256H | Missense Mutation (SNP) | VAF 38/181 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as rs756625630, COSV53908987; called by muse, mutect2, varscan2
- PCDHGA9 | c.2157G>T p.W719C | Missense Mutation (SNP) | VAF 32/119 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.982); catalogued as COSV53909016; called by muse, mutect2, varscan2
- PCYT1B | c.611A>T p.D204V | Missense Mutation (SNP) | VAF 74/173 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV63264203; called by muse, mutect2, varscan2
- PDIA2 | c.187C>A p.L63M | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.892); catalogued as COSV51984142; called by muse, mutect2, varscan2
- PDILT | c.1033G>T p.A345S | Missense Mutation (SNP) | VAF 63/339 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.101); catalogued as rs747898472, COSV56699985, COSV56701372; called by muse, mutect2, varscan2
- PDZD9 | c.395T>G p.V132G (on ENST00000424898 / NM_001363519.1; = p.V72G on NM_173806.4) | Missense Mutation (SNP) | VAF 40/146 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.446); catalogued as COSV51671039; called by muse, mutect2, varscan2
- PDZRN3 | c.2867G>T p.G956V | Missense Mutation (SNP) | VAF 35/125 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747778714, COSV55192349, COSV99731424; called by muse, mutect2, varscan2
- PDZRN3 | c.2777G>C p.R926P | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55192373; called by muse, mutect2, varscan2
- PECR | c.478C>T p.P160S | Missense Mutation (SNP) | VAF 34/129 reads (26%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV54733625; called by muse, mutect2, varscan2
- PHACTR3 | c.824C>T p.P275L | Missense Mutation (SNP) | VAF 23/224 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.778); catalogued as COSV63025612; called by muse, mutect2
- PHLDA1 | c.734G>T p.R245L | Missense Mutation (SNP) | VAF 61/135 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.79); catalogued as COSV56996736, COSV56996832; called by muse, mutect2, varscan2
- PI4KB | c.300G>T p.E100D (on ENST00000368873 / NM_001369623.1; = p.E112D on NM_002651.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 49/240 reads (20%) | SIFT tolerated, low confidence (0.27); PolyPhen possibly damaging (0.584); catalogued as COSV55015593; called by muse, mutect2, varscan2
- PIK3CG | c.2391+1G>T p.X797_splice | Splice Site (SNP) | VAF 14/112 reads (13%) | catalogued as COSV100782643; called by muse, varscan2
- PIP5K1A | c.343G>T p.V115L (on ENST00000368888 / NM_001135638.2; = p.V102L on NM_003557.3) | Missense Mutation (SNP) | VAF 69/252 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.303); catalogued as COSV62957543; called by muse, mutect2, varscan2
- PKHD1L1 | c.8535C>A p.H2845Q | Missense Mutation (SNP) | VAF 29/82 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as COSV65738596; called by muse, mutect2, varscan2
- PKNOX2 | c.1076C>A p.A359D | Missense Mutation (SNP) | VAF 52/520 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.029); catalogued as COSV53541886; called by muse, mutect2
- PLB1 | c.4050C>A p.F1350L | Missense Mutation (SNP) | VAF 23/230 reads (10%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.996); catalogued as COSV59820331; called by muse, varscan2
- PLCB1 | c.3409G>T p.D1137Y | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100569763; called by muse, mutect2
- PLCE1 | c.2575C>A p.Q859K | Missense Mutation (SNP) | VAF 39/121 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.155); catalogued as COSV99593866; called by muse, mutect2, varscan2
- PLCE1 | c.2576A>G p.Q859R | Missense Mutation (SNP) | VAF 40/123 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.347); catalogued as COSV99593873; called by muse, mutect2, varscan2
- PLEC | c.11719G>A p.G3907S (on ENST00000322810 / NM_201380.4; = p.G3797S on NM_000445.5) | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1444612790, COSV59609645; called by muse, mutect2, varscan2
- PLEKHG3 | c.2105A>G p.N702S (on ENST00000394691; = p.N758S on NM_001308147.2) | Missense Mutation (SNP) | VAF 79/339 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs757599300, COSV55978066; called by muse, mutect2, varscan2
- PLPPR4 | c.926A>C p.Y309S | Missense Mutation (SNP) | VAF 28/206 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as COSV64564647; called by muse, mutect2, varscan2
- PLXND1 | c.4994-1G>C p.X1665_splice | Splice Site (SNP) | VAF 29/114 reads (25%) | catalogued as COSV60709986; called by muse, mutect2, varscan2
- PPP1R12B | c.915G>T p.Q305H | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV61113940; called by muse, mutect2, varscan2
- PPP2R1A | c.1115A>T p.Q372L | Missense Mutation (SNP) | VAF 40/150 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV59042818; called by muse, mutect2, varscan2
- PPP3R2 | c.402C>A p.D134E | Missense Mutation (SNP) | VAF 16/168 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.858); catalogued as COSV62451450; called by muse, mutect2, varscan2
- PPP4R3A | c.2336G>T p.G779V (on ENST00000554943 / NM_001366432.1; = p.G766V on NM_001284280.1) | Missense Mutation (SNP) | VAF 61/418 reads (15%) | SIFT tolerated (0.46); PolyPhen benign (0.127); catalogued as COSV61503680; called by muse, mutect2, varscan2
- PRAMEF19 | c.1141A>G p.T381A | Missense Mutation (SNP) | VAF 102/905 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.869); catalogued as rs763111416; called by muse, mutect2, varscan2
- PRDM16 | c.1870G>T p.D624Y | Missense Mutation (SNP) | VAF 18/204 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV54580933, COSV54607748, COSV54607942; called by muse, mutect2
- PRDM5 | c.1657G>A p.A553T | Missense Mutation (SNP) | VAF 40/162 reads (25%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.61); catalogued as COSV53356651; called by muse, mutect2, varscan2
- PRELP | c.83C>A p.P28H | Missense Mutation (SNP) | VAF 87/269 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.436); catalogued as COSV58115097, COSV58116639; called by muse, mutect2, varscan2
- PRKCB | c.528C>A p.L176= | Splice Region (SNP) | VAF 26/187 reads (14%) | catalogued as COSV57768867; called by muse, mutect2, varscan2
- PRKD1 | c.536G>T p.G179V | Missense Mutation (SNP) | VAF 74/295 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV59560745; called by muse, mutect2, varscan2
- PROC | c.549T>A p.C183* | Nonsense Mutation (SNP) | VAF 35/135 reads (26%) | catalogued as COSV52164948; called by muse, mutect2, varscan2
- PROM2 | c.1357G>T p.G453C | Missense Mutation (SNP) | VAF 27/142 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58296944; called by muse, mutect2, varscan2
- PRPF38B | c.559-1G>T p.X187_splice | Splice Site (SNP) | VAF 29/135 reads (21%) | catalogued as COSV64223543; called by muse, mutect2, varscan2
- PRPS1L1 | c.373A>T p.I125F | Missense Mutation (SNP) | VAF 81/240 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); catalogued as COSV72649831; called by muse, mutect2, varscan2
- PSD | c.1417G>C p.A473P | Missense Mutation (SNP) | VAF 40/115 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.296); catalogued as COSV50042276, COSV50065773; called by muse, mutect2, varscan2
- PSG7 | c.865C>T p.R289C | Missense Mutation (SNP) | VAF 109/710 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.594); catalogued as rs775658996, COSV68444433; called by muse, mutect2, varscan2
- PTAFR | c.865G>T p.D289Y | Missense Mutation (SNP) | VAF 44/161 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59536158, COSV59536571; called by muse, mutect2, varscan2
- PTCHD4 | c.2074G>C p.V692L | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.84); catalogued as COSV59778280, COSV59779193; called by muse, mutect2, varscan2
- PTGFR | c.722G>C p.R241T | Missense Mutation (SNP) | VAF 40/160 reads (25%) | SIFT tolerated (0.31); PolyPhen benign (0.047); catalogued as COSV66114511, COSV66116048; called by muse, mutect2, varscan2
- PTGFRN | c.1847T>C p.L616P | Missense Mutation (SNP) | VAF 23/185 reads (12%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.987); catalogued as COSV67797915; called by muse, mutect2, varscan2
- PTPRD | c.3745C>A p.P1249T | Missense Mutation (SNP) | VAF 16/168 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV61931781; called by muse, mutect2
- PTPRZ1 | c.658C>G p.L220V | Missense Mutation (SNP) | VAF 128/374 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs1029352780, COSV66431656; called by muse, mutect2, varscan2
- PUM2 | c.1679G>A p.G560D | Missense Mutation (SNP) | VAF 31/138 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57578403; called by muse, mutect2, varscan2
- PUM3 | c.1189-1G>T p.X397_splice | Splice Site (SNP) | VAF 9/83 reads (11%) | catalogued as COSV67395793; called by muse, mutect2, varscan2
- PXDN | c.2463G>T p.W821C | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53228074; called by muse, mutect2
- QTRT1 | c.682G>C p.G228R | Missense Mutation (SNP) | VAF 63/202 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748388439, COSV51550332, COSV99139017; called by muse, mutect2, varscan2
- R3HDM1 | c.794A>T p.K265I | Missense Mutation (SNP) | VAF 37/187 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51521501; called by muse, mutect2, varscan2
- RAB3C | c.377C>A p.T126N | Missense Mutation (SNP) | VAF 26/158 reads (16%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.902); catalogued as COSV51432144; called by muse, mutect2, varscan2
- RAB3GAP2 | c.149del p.G50Efs*41 | Frame Shift Del (DEL) | VAF 38/252 reads (15%) | catalogued as COSV52966745; called by mutect2, pindel, varscan2
- RABGEF1 | c.776G>T p.R259L (on ENST00000439720 / NM_001287061.2; = p.R246L on NM_014504.3 and 29 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as COSV53161033; called by muse, mutect2, varscan2
- RABL3 | c.463A>T p.T155S | Missense Mutation (SNP) | VAF 168/684 reads (25%) | SIFT tolerated (0.79); PolyPhen benign (0.023); catalogued as COSV56335162; called by muse, mutect2, varscan2
- RAG1 | c.2683G>T p.V895L | Missense Mutation (SNP) | VAF 28/199 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); catalogued as COSV55024101; called by muse, mutect2, varscan2
- RALGPS1 | c.1339G>T p.G447W | Missense Mutation (SNP) | VAF 11/103 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52217279; called by muse, mutect2, varscan2
- RALGPS2 | c.949G>T p.A317S | Missense Mutation (SNP) | VAF 36/148 reads (24%) | SIFT tolerated (0.33); PolyPhen benign (0.045); catalogued as COSV100243628; called by muse, mutect2, varscan2
- RANGAP1 | c.534G>T p.K178N | Missense Mutation (SNP) | VAF 43/127 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.266); catalogued as COSV62362614; called by muse, mutect2, varscan2
- RAPGEF2 | c.3487G>T p.V1163L | Missense Mutation (SNP) | VAF 42/196 reads (21%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); catalogued as COSV52425451; called by muse, mutect2, varscan2
- RAPGEF3 | c.848G>T p.W283L (on ENST00000389212; = p.W241L on NM_006105.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 82/180 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50198845; called by muse, mutect2, varscan2
- RASGRF2 | c.1996C>A p.L666M | Missense Mutation (SNP) | VAF 97/476 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54124012; called by muse, varscan2
- RASGRF2 | c.2045T>C p.L682P | Missense Mutation (SNP) | VAF 76/272 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV54124024; called by muse, varscan2
- RASSF2 | c.581G>T p.R194L | Missense Mutation (SNP) | VAF 20/105 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs369276882, COSV65081772; called by muse, mutect2, varscan2
- RBBP6 | c.1632G>C p.R544S | Missense Mutation (SNP) | VAF 36/219 reads (16%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.987); catalogued as COSV60503656; called by muse, mutect2, varscan2
- RBM47 | c.481A>T p.M161L | Missense Mutation (SNP) | VAF 42/152 reads (28%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV55930810; called by muse, mutect2, varscan2
- RBM7 | c.436G>T p.V146L | Missense Mutation (SNP) | VAF 38/103 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.236); catalogued as rs1197876807, COSV64955434; called by muse, mutect2, varscan2
- RCC2 | c.7A>T p.R3W | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.035); catalogued as COSV64905359; called by muse, mutect2
- RDH16 | c.940G>T p.A314S | Missense Mutation (SNP) | VAF 46/113 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.142); catalogued as COSV100660177, COSV62457935; called by muse, mutect2, varscan2
- REC114 | c.680C>A p.S227Y | Missense Mutation (SNP) | VAF 45/163 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV58521596; called by muse, mutect2, varscan2
- REG3A | c.374G>T p.S125I | Missense Mutation (SNP) | VAF 58/230 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.129); catalogued as COSV59408670; called by muse, varscan2
- REV1 | c.354C>G p.I118M | Missense Mutation (SNP) | VAF 11/204 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51482430; called by muse, mutect2
- RFC3 | c.661A>T p.R221* | Nonsense Mutation (SNP) | VAF 11/102 reads (11%) | catalogued as COSV66296524; called by muse, mutect2, varscan2
- RGS22 | c.2123A>G p.Y708C | Missense Mutation (SNP) | VAF 26/171 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760394259, COSV62658145; called by muse, varscan2
- RGS7BP | c.327C>G p.I109M | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.991); catalogued as COSV61833723; called by muse, mutect2
- RHOJ | c.151G>A p.V51M | Missense Mutation (SNP) | VAF 17/128 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.447); catalogued as rs921202045, COSV57456941; called by muse, mutect2, varscan2
- RICTOR | c.4258G>T p.G1420C | Missense Mutation (SNP) | VAF 48/402 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV57118145, COSV57121123; called by muse, mutect2, varscan2
- RICTOR | c.172G>T p.G58C | Missense Mutation (SNP) | VAF 58/369 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.503); catalogued as COSV57118160, COSV99704618; called by muse, mutect2, varscan2
- RIMS1 | c.379G>T p.G127W | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53442305, COSV53450164; called by muse, mutect2, varscan2
- RIMS2 | c.2233A>G p.I745V (on ENST00000666250 / NM_001348490.2; = p.I553V on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/180 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV51658077; called by muse, mutect2
- RIPOR2 | c.1906G>C p.D636H | Missense Mutation (SNP) | VAF 29/117 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV52418052; called by muse, mutect2, varscan2
- ROR2 | c.1821del p.S608Afs*15 | Frame Shift Del (DEL) | VAF 37/136 reads (27%) | catalogued as COSV65219314; called by mutect2, pindel, varscan2
- RP1 | c.1572T>G p.D524E | Missense Mutation (SNP) | VAF 10/117 reads (9%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV55111517; called by muse, mutect2
- RPS6KL1 | c.845G>T p.R282M | Missense Mutation (SNP) | VAF 44/169 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0.19); catalogued as COSV63580733; called by muse, mutect2, varscan2
- RSPO2 | c.199G>T p.G67W | Missense Mutation (SNP) | VAF 93/245 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV52639444; called by muse, mutect2, varscan2
- RUVBL1 | c.141G>T p.E47D | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV59475136; called by muse, mutect2, varscan2
- SAMHD1 | c.1090C>T p.H364Y | Missense Mutation (SNP) | VAF 32/109 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.068); catalogued as rs761616206, COSV53428585; called by muse, mutect2, varscan2
- SAPCD2 | c.831+1G>A p.X277_splice | Splice Site (SNP) | VAF 10/75 reads (13%) | catalogued as rs765827159, COSV68836377; called by muse, mutect2, varscan2
- SCAF11 | c.2711G>T p.G904V | Missense Mutation (SNP) | VAF 218/518 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.039); catalogued as COSV65475262; called by muse, mutect2, varscan2
- SCG2 | c.739G>T p.G247* | Nonsense Mutation (SNP) | VAF 120/499 reads (24%) | catalogued as COSV100544872, COSV59539229; called by muse, mutect2, varscan2
- SCN1A | c.2509G>T p.G837C (on ENST00000303395 / NM_001202435.3; = p.G826C on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/99 reads (35%) | SIFT tolerated (0.22); PolyPhen benign (0.026); catalogued as COSV57662590; called by muse, mutect2, varscan2
- SCN9A | c.2822A>T p.Q941L (on ENST00000303354; = p.Q930L on NM_002977.3) | Missense Mutation (SNP) | VAF 58/363 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.672); catalogued as COSV57602235; called by muse, mutect2, varscan2
- SCRN1 | c.1066G>A p.A356T | Missense Mutation (SNP) | VAF 34/380 reads (9%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV54128723; called by muse, mutect2
- SCRN1 | c.622G>C p.A208P | Missense Mutation (SNP) | VAF 87/482 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54128739; called by muse, mutect2, varscan2
- SDK1 | c.3625G>T p.V1209L | Missense Mutation (SNP) | VAF 18/196 reads (9%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as COSV67358609; called by muse, mutect2
- SEC13 | c.258G>C p.W86C (on ENST00000350697 / NM_183352.3; = p.W89C on NM_030673.4) | Missense Mutation (SNP) | VAF 73/257 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61601343, COSV61602328; called by muse, mutect2, varscan2
- SEC31A | c.3500C>A p.T1167N (on ENST00000355196 / NM_001318120.1; = p.T1128N on NM_016211.4) | Missense Mutation (SNP) | VAF 25/131 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.072); catalogued as COSV52342095; called by muse, mutect2, varscan2
- SEMA3A | c.926A>G p.Q309R | Missense Mutation (SNP) | VAF 28/100 reads (28%) | SIFT tolerated (0.39); PolyPhen benign (0.08); catalogued as COSV54863214, COSV54870165; called by muse, mutect2, varscan2
- SERPINA9 | c.151T>A p.F51I | Missense Mutation (SNP) | VAF 37/136 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54073061; called by muse, mutect2, varscan2
- SERPINA9 | c.38G>C p.G13A | Missense Mutation (SNP) | VAF 52/187 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.391); catalogued as COSV54073079; called by muse, mutect2, varscan2
- SERPINB12 | c.504T>A p.G168= | Splice Region (SNP) | VAF 14/232 reads (6%) | catalogued as COSV54032267; called by muse, mutect2
- SERTAD2 | c.307G>T p.A103S | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.054); catalogued as COSV57639728; called by muse, mutect2, varscan2
- SETBP1 | c.3815G>C p.S1272T | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.049); catalogued as COSV56314588; called by muse, mutect2, varscan2
- SEZ6L2 | c.1209-1G>A p.X403_splice (on ENST00000308713 / NM_001114099.3; = p.X333_splice on NM_012410.4) | Splice Site (SNP) | VAF 19/106 reads (18%) | catalogued as rs769341834, COSV58097601; called by muse, varscan2
- SH3GL3 | c.301G>T p.G101W | Missense Mutation (SNP) | VAF 40/124 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs559656402, COSV61053890, COSV61056992; called by muse, varscan2
- SHOC1 | c.89C>A p.T30N | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT tolerated (0.34); PolyPhen benign (0.018); catalogued as COSV59498205; called by muse, mutect2, varscan2
- SHPRH | c.2378G>C p.R793P | Missense Mutation (SNP) | VAF 34/107 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV51605525; called by muse, mutect2, varscan2
- SHROOM4 | c.3566G>A p.G1189D | Missense Mutation (SNP) | VAF 7/80 reads (9%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as COSV56785390; called by muse, mutect2
- SIGLEC10 | c.2062C>T p.Q688* | Nonsense Mutation (SNP) | VAF 53/166 reads (32%) | catalogued as COSV59479537; called by muse, mutect2, varscan2
- SIGLEC8 | c.121C>A p.L41M | Missense Mutation (SNP) | VAF 59/221 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV58472444; called by muse, mutect2, varscan2
- SIGLEC9 | c.794G>T p.G265V | Missense Mutation (SNP) | VAF 74/257 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51582875; called by muse, mutect2, varscan2
- SKAP2 | c.313C>T p.Q105* | Nonsense Mutation (SNP) | VAF 14/94 reads (15%) | catalogued as COSV61721770; called by muse, mutect2, varscan2
- SLC10A2 | c.346G>T p.A116S | Missense Mutation (SNP) | VAF 16/167 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.129); catalogued as COSV55357451; called by muse, mutect2
- SLC10A7 | c.335G>T p.G112V | Missense Mutation (SNP) | VAF 27/104 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.186); catalogued as COSV53880821; called by muse, mutect2, varscan2
- SLC12A1 | c.391C>A p.L131M | Missense Mutation (SNP) | VAF 39/170 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57708450; called by muse, mutect2, varscan2
- SLC17A9 | c.368T>C p.F123S | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT tolerated (0.25); PolyPhen benign (0.014); catalogued as rs1283808937, COSV64846909; called by muse, mutect2, varscan2
- SLC22A6 | c.683A>T p.Y228F | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT tolerated (0.34); PolyPhen benign (0.253); catalogued as COSV64559895; called by muse, mutect2, varscan2
- SLC26A3 | c.275T>C p.L92S | Missense Mutation (SNP) | VAF 9/149 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV60639050; called by muse, mutect2
- SLC30A3 | c.371G>A p.W124* | Nonsense Mutation (SNP) | VAF 33/118 reads (28%) | catalogued as COSV51984206; called by muse, mutect2, varscan2
- SLC43A2 | c.1704C>A p.F568L | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.084); catalogued as COSV56767848, COSV56772073; called by muse, mutect2
- SLC44A1 | c.1585G>T p.V529L | Missense Mutation (SNP) | VAF 62/254 reads (24%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.997); catalogued as COSV58262544; called by muse, mutect2, varscan2
- SLC4A3 | c.947G>A p.R316Q | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.707); catalogued as rs766023938, COSV56091989; called by muse, mutect2, varscan2
- SLC5A11 | c.644C>T p.A215V | Missense Mutation (SNP) | VAF 73/444 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV61740384; called by muse, mutect2, varscan2
- SLC5A7 | c.29C>A p.A10D | Missense Mutation (SNP) | VAF 34/185 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV50889271; called by muse, mutect2, varscan2
- SLC6A19 | c.653C>T p.T218I | Missense Mutation (SNP) | VAF 41/237 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58669857; called by muse, mutect2, varscan2
- SLC6A5 | c.712G>T p.A238S | Missense Mutation (SNP) | VAF 47/171 reads (27%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.593); catalogued as COSV54224033, COSV54224296; called by muse, mutect2, varscan2
- SLCO2B1 | c.985C>A p.P329T | Missense Mutation (SNP) | VAF 37/101 reads (37%) | SIFT tolerated (0.4); PolyPhen benign (0.013); catalogued as COSV56933378; called by muse, mutect2, varscan2
- SLIT1 | c.2080G>A p.G694R | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56581393; called by muse, mutect2, varscan2
- SLITRK6 | c.1355C>A p.P452Q | Missense Mutation (SNP) | VAF 19/161 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.678); catalogued as COSV68389526; called by muse, mutect2, varscan2
- SMARCA4 | c.4015G>T p.E1339* | Nonsense Mutation (SNP) | VAF 7/18 reads (39%) | catalogued as COSV60788531, COSV60806990; called by muse, mutect2, varscan2
- SMARCAD1 | c.3020G>T p.G1007V | Missense Mutation (SNP) | VAF 52/369 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.299); catalogued as COSV62773170; called by muse, mutect2, varscan2
- SMC4 | c.349A>T p.S117C | Missense Mutation (SNP) | VAF 88/267 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58445575; called by muse, mutect2, varscan2
- SMOC1 | c.1205G>T p.R402L | Missense Mutation (SNP) | VAF 43/372 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as rs1455506717, COSV62759766, COSV62760557; called by muse, mutect2, varscan2
- SMURF1 | c.1918T>G p.L640V | Missense Mutation (SNP) | VAF 13/114 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV62815787; called by muse, mutect2
- SNIP1 | c.910G>T p.A304S | Missense Mutation (SNP) | VAF 45/281 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56165765; called by muse, mutect2, varscan2
- SORCS3 | c.982C>G p.R328G | Missense Mutation (SNP) | VAF 67/257 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.734); catalogued as COSV100865177, COSV63803722; called by muse, mutect2, varscan2
- SOX5 | c.362G>T p.G121V | Missense Mutation (SNP) | VAF 28/211 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.649); catalogued as COSV58620713; called by muse, mutect2, varscan2
- SPEF2 | c.1535G>T p.G512V | Missense Mutation (SNP) | VAF 29/181 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV61544933; called by muse, mutect2, varscan2
- SPEG | c.7937G>T p.R2646L | Missense Mutation (SNP) | VAF 52/169 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.649); catalogued as rs201143360, COSV56664385, COSV56671387; called by muse, mutect2, varscan2
- SPN | c.99G>T p.L33F | Missense Mutation (SNP) | VAF 66/281 reads (23%) | SIFT tolerated (0.42); PolyPhen benign (0.423); catalogued as COSV64070009; called by muse, mutect2, varscan2
- SPRR1B | c.195C>A p.C65* | Nonsense Mutation (SNP) | VAF 70/360 reads (19%) | catalogued as COSV61067471; called by muse, mutect2, varscan2
- SPTBN1 | c.6790G>T p.V2264L | Missense Mutation (SNP) | VAF 48/353 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.12); catalogued as COSV61686131; called by muse, mutect2, varscan2
- SPTBN2 | c.901A>T p.M301L | Missense Mutation (SNP) | VAF 14/119 reads (12%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs897181468, COSV59448114; called by muse, mutect2, varscan2
- SQSTM1 | c.329G>T p.R110L | Missense Mutation (SNP) | VAF 38/148 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.122); catalogued as COSV62434318; called by muse, mutect2, varscan2
- SRGAP2 | c.1646C>T p.A549V (on ENST00000624873 / NM_001170637.4; = p.A550V on NM_015326.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 37/305 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.034); catalogued as COSV55333992; called by muse, mutect2, varscan2
- SRGAP2 | c.3161G>T p.G1054V (on ENST00000624873 / NM_001170637.4; = p.G1055V on NM_015326.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 79/326 reads (24%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.101); catalogued as COSV55334005; called by muse, mutect2, varscan2
- STARD13 | c.839G>T p.R280L (on ENST00000336934 / NM_001243476.3; = p.R162L on NM_052851.3) | Missense Mutation (SNP) | VAF 15/193 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.081); catalogued as COSV55227890; called by muse, mutect2
- STARD13 | c.464G>T p.R155L (on ENST00000336934 / NM_001243476.3; = p.R37L on NM_052851.3) | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as COSV55227681, COSV55227908; called by muse, mutect2, varscan2
- STARD7 | c.841G>C p.E281Q | Missense Mutation (SNP) | VAF 68/249 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.657); catalogued as COSV61525174; called by muse, mutect2, varscan2
- STEAP4 | c.182G>A p.G61D | Missense Mutation (SNP) | VAF 42/273 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.172); catalogued as COSV57328271; called by muse, mutect2, varscan2
- STIM1 | c.1183C>T p.H395Y | Missense Mutation (SNP) | VAF 41/142 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV56152127; called by muse, mutect2, varscan2
- STK31 | c.2473C>A p.P825T | Missense Mutation (SNP) | VAF 48/365 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV63454440; called by muse, mutect2, varscan2
- STPG2 | c.1369G>A p.D457N | Missense Mutation (SNP) | VAF 32/188 reads (17%) | SIFT tolerated, low confidence (0.9); PolyPhen benign (0); catalogued as COSV54787871; called by muse, mutect2, varscan2
- STXBP1 | c.235C>G p.P79A | Missense Mutation (SNP) | VAF 49/416 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as rs1462181047, COSV64812224; called by muse, mutect2, varscan2
- SULT2A1 | c.716T>A p.V239E | Missense Mutation (SNP) | VAF 57/190 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.457); catalogued as COSV55764269; called by muse, mutect2, varscan2
- SYCP2L | c.1541C>A p.T514N | Missense Mutation (SNP) | VAF 7/112 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.49); catalogued as COSV51650478; called by muse, mutect2
- SYNPO2 | c.847C>T p.R283W | Missense Mutation (SNP) | VAF 40/141 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as rs914334727, COSV61107476; called by muse, mutect2, varscan2
- SYNPO2 | c.2045G>T p.G682V | Missense Mutation (SNP) | VAF 15/119 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61107491; called by muse, mutect2, varscan2
- SYT6 | c.1399G>T p.V467L (on ENST00000610222 / NM_001366225.1; = p.V382L on NM_205848.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/232 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.096); catalogued as COSV65772698; called by muse, mutect2, varscan2
- SYTL2 | c.252A>T p.A84= | Splice Region (SNP) | VAF 107/298 reads (36%) | catalogued as COSV60356417; called by muse, mutect2, varscan2
- TAF1L | c.1792G>T p.G598C | Missense Mutation (SNP) | VAF 104/443 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV54259118, COSV99644232; called by muse, mutect2, varscan2
- TAF1L | c.1791G>T p.Q597H | Missense Mutation (SNP) | VAF 103/446 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.18); catalogued as COSV54262769, COSV99644233; called by muse, mutect2, varscan2
- TAS1R1 | c.2439C>A p.Y813* | Nonsense Mutation (SNP) | VAF 29/169 reads (17%) | catalogued as COSV59839437; called by muse, mutect2, varscan2
- TBX22 | c.79C>A p.P27T | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as COSV64785128; called by muse, mutect2, varscan2
- TBX3 | c.1069G>T p.A357S (on ENST00000257566 / NM_016569.4; = p.A337S on NM_005996.4) | Missense Mutation (SNP) | VAF 60/167 reads (36%) | SIFT tolerated (0.76); PolyPhen benign (0.124); catalogued as COSV57469656; called by muse, mutect2, varscan2
- TBX5 | c.838G>A p.A280T | Missense Mutation (SNP) | VAF 18/266 reads (7%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV59858835; called by muse, mutect2
- TCEA2 | c.76G>T p.G26* | Nonsense Mutation (SNP) | VAF 31/316 reads (10%) | catalogued as COSV58657286; called by muse, mutect2
- TCF7L2 | c.1319-2A>T p.X440_splice (on ENST00000355995 / NM_001367943.1; = p.X417_splice on NM_030756.5) | Splice Site (SNP) | VAF 12/150 reads (8%) | catalogued as COSV99525401; called by muse, mutect2
- TENM2 | c.1729C>A p.P577T (on ENST00000518659 / NM_001122679.2; = p.P345T on NM_001080428.3) | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.14); catalogued as COSV69124046; called by muse, mutect2, varscan2
- TENM4 | c.2570G>T p.C857F | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as COSV53612327; called by muse, mutect2, varscan2
- TENT5A | c.1115A>T p.H372L | Missense Mutation (SNP) | VAF 7/132 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV60787411; called by muse, mutect2
- TESPA1 | c.889C>T p.R297* (on ENST00000316577 / NM_001098815.3; = p.R159* on NM_014796.2 and 5 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 55/133 reads (41%) | catalogued as rs764857918, COSV57257521; called by muse, mutect2, varscan2
- TET1 | c.5352G>T p.K1784N | Missense Mutation (SNP) | VAF 20/156 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as rs1454252323, COSV65382496; called by muse, mutect2, varscan2
- TET1 | c.5698G>T p.G1900C | Missense Mutation (SNP) | VAF 17/168 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65382501; called by muse, mutect2, varscan2
- TEX13B | c.245A>T p.Q82L | Missense Mutation (SNP) | VAF 106/243 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV57202254; called by muse, mutect2, varscan2
- TEX2 | c.1798G>T p.E600* | Nonsense Mutation (SNP) | VAF 63/252 reads (25%) | catalogued as COSV51978037; called by muse, mutect2, varscan2
- TFAP2B | c.212C>A p.P71Q | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.145); catalogued as COSV53825533; called by muse, mutect2
- TFPT | c.13C>G p.Q5E | Missense Mutation (SNP) | VAF 10/182 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.764); catalogued as COSV58084653; called by muse, mutect2
- TG | c.3398A>G p.E1133G | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.419); catalogued as COSV55067050; called by muse, mutect2
- TG | c.7620C>A p.Y2540* | Nonsense Mutation (SNP) | VAF 96/230 reads (42%) | catalogued as COSV55067077; called by muse, mutect2, varscan2
- TGFBR3 | c.2278G>T p.E760* | Nonsense Mutation (SNP) | VAF 74/270 reads (27%) | catalogued as COSV53022438; called by muse, mutect2, varscan2
- TGM4 | c.1597C>A p.Q533K | Missense Mutation (SNP) | VAF 31/90 reads (34%) | SIFT tolerated (0.22); PolyPhen benign (0.05); catalogued as COSV56092980; called by muse, mutect2, varscan2
- TGM7 | c.46A>T p.S16C | Missense Mutation (SNP) | VAF 28/133 reads (21%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.923); catalogued as COSV71772602; called by muse, mutect2, varscan2
- THSD7A | c.1596G>T p.Q532H | Missense Mutation (SNP) | VAF 28/90 reads (31%) | SIFT tolerated (0.24); PolyPhen benign (0.017); catalogued as COSV70261105; called by muse, mutect2, varscan2
- TIGD4 | c.457G>T p.G153C | Missense Mutation (SNP) | VAF 35/160 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.156); catalogued as COSV100427862, COSV58549072; called by muse, mutect2, varscan2
- TIMELESS | c.3454G>T p.E1152* | Nonsense Mutation (SNP) | VAF 321/716 reads (45%) | catalogued as COSV57509473; called by muse, mutect2, varscan2
- TIMM17B | c.299G>T p.G100V | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV54429434, COSV99504572; called by muse, mutect2
- TKTL2 | c.989C>A p.A330D | Missense Mutation (SNP) | VAF 90/391 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV54917715, COSV54919539; called by muse, mutect2, varscan2
- TLL1 | c.1963A>T p.R655* | Nonsense Mutation (SNP) | VAF 57/193 reads (30%) | catalogued as COSV50263459, COSV50321640; called by muse, mutect2, varscan2
- TNC | c.3435T>G p.Y1145* | Nonsense Mutation (SNP) | VAF 47/481 reads (10%) | catalogued as COSV60781231; called by muse, mutect2, varscan2
- TNRC6C | c.2053G>A p.V685M | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.935); catalogued as rs1385285782, COSV56941304; called by muse, mutect2, varscan2
- TOPORS | c.277G>C p.V93L | Missense Mutation (SNP) | VAF 17/195 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.202); catalogued as COSV62116305; called by muse, mutect2
- TP53 | c.217del p.V73Wfs*50 | Frame Shift Del (DEL) | VAF 52/180 reads (29%) | catalogued as CD109812, COSV53023392, COSV53359933, COSV53361901, COSV53625318, COSV99409681; called by mutect2, varscan2
- TPO | c.2656G>A p.E886K | Missense Mutation (SNP) | VAF 50/166 reads (30%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.156); catalogued as COSV61096265; called by muse, mutect2, varscan2
- TRAM1 | c.135A>T p.K45N | Missense Mutation (SNP) | VAF 40/111 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.138); catalogued as COSV51596845; called by muse, mutect2, varscan2
- TRAM1L1 | c.442G>T p.D148Y | Missense Mutation (SNP) | VAF 50/196 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.949); catalogued as COSV60291369; called by muse, mutect2, varscan2
- TRANK1 | c.8203G>A p.G2735S | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT tolerated, low confidence (0.89); PolyPhen benign (0); catalogued as rs765419817, COSV57143035, COSV57160597; called by muse, mutect2, varscan2
- TRIB2 | c.1001T>A p.M334K | Missense Mutation (SNP) | VAF 15/99 reads (15%) | SIFT tolerated (0.87); PolyPhen benign (0.05); catalogued as COSV99330952; called by muse, mutect2, varscan2
- TRIB2 | c.1002G>T p.M334I | Missense Mutation (SNP) | VAF 16/101 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as COSV50223936, COSV99330959; called by muse, mutect2, varscan2
- TRIM55 | c.1236G>A p.Q412= | Splice Region (SNP) | VAF 30/190 reads (16%) | catalogued as COSV99396586; called by muse, mutect2, varscan2
- TRIM55 | c.1236+1G>T p.X412_splice | Splice Site (SNP) | VAF 31/187 reads (17%) | catalogued as COSV52545690, COSV99396591; called by muse, mutect2, varscan2
- TRIM71 | c.2449C>T p.R817W | Missense Mutation (SNP) | VAF 10/268 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67470262; called by muse, mutect2
- TRIM75P | c.1316C>A p.T439N | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT tolerated (0.32); PolyPhen benign (0.421); catalogued as COSV72295808; called by muse, mutect2, varscan2
- TRIML1 | c.1386C>A p.C462* | Nonsense Mutation (SNP) | VAF 29/175 reads (17%) | catalogued as COSV60193516; called by muse, mutect2, varscan2
- TRMT2B | c.709G>A p.G237R | Missense Mutation (SNP) | VAF 72/190 reads (38%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.635); catalogued as COSV58618627; called by muse, mutect2, varscan2
- TRPM4 | c.2953G>T p.V985L | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as COSV53259986; called by muse, mutect2, varscan2
- TRPV5 | c.758C>A p.T253N | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.84); catalogued as COSV54683514; called by muse, mutect2, varscan2
- TSPAN33 | c.581C>A p.P194H | Missense Mutation (SNP) | VAF 186/589 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.2); catalogued as COSV56825583; called by muse, mutect2, varscan2
- TXK | c.206G>A p.R69Q | Missense Mutation (SNP) | VAF 19/311 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.054); catalogued as rs776450131, COSV51912900; called by muse, mutect2
- TXNDC12 | c.463C>T p.Q155* | Nonsense Mutation (SNP) | VAF 22/136 reads (16%) | catalogued as COSV65412962; called by muse, mutect2, varscan2
- UCMA | c.376G>T p.G126C | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66321313, COSV66321927; called by muse, mutect2, varscan2
- UGDH | c.166G>T p.G56* | Nonsense Mutation (SNP) | VAF 30/213 reads (14%) | catalogued as COSV57096859; called by muse, mutect2, varscan2
- UGT2A1 | c.72G>T p.L24F | Missense Mutation (SNP) | VAF 18/111 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54138765; called by muse, mutect2, varscan2
- UGT2A3 | c.827G>A p.G276E | Missense Mutation (SNP) | VAF 32/153 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV52359053; called by muse, mutect2, varscan2
- ULK4 | c.1799C>A p.A600D | Missense Mutation (SNP) | VAF 18/214 reads (8%) | SIFT tolerated (0.28); PolyPhen benign (0.021); catalogued as COSV57200805; called by muse, mutect2
- UMOD | c.139G>T p.V47F | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.474); catalogued as COSV56774007; called by muse, mutect2, varscan2
- UMODL1 | c.1411G>T p.V471L | Missense Mutation (SNP) | VAF 80/310 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.079); catalogued as rs150059583, COSV61159437; called by muse, mutect2, varscan2
- UNC13C | c.2645T>A p.M882K | Missense Mutation (SNP) | VAF 47/152 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.261); catalogued as COSV52848094; called by muse, mutect2, varscan2
- UNC5B | c.782G>T p.R261L | Missense Mutation (SNP) | VAF 20/168 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.939); catalogued as COSV58974958; called by muse, mutect2, varscan2
- USF3 | c.4761C>A p.N1587K | Missense Mutation (SNP) | VAF 30/113 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.138); catalogued as COSV57070355; called by muse, mutect2, varscan2
- USH2A | c.6949G>T p.G2317C | Missense Mutation (SNP) | VAF 33/234 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56335022; called by muse, mutect2, varscan2
- USH2A | c.1493C>A p.T498N | Missense Mutation (SNP) | VAF 92/336 reads (27%) | SIFT tolerated (0.34); PolyPhen benign (0.062); catalogued as COSV56335038; called by muse, mutect2, varscan2
- USHBP1 | c.463G>A p.G155R | Missense Mutation (SNP) | VAF 65/197 reads (33%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.659); catalogued as rs528877755, COSV53102475; called by muse, mutect2, varscan2
- USP6 | c.1735G>A p.G579R | Missense Mutation (SNP) | VAF 24/103 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV51476237; called by muse, mutect2, varscan2
- USP8 | c.272G>T p.G91V | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56162742; called by muse, mutect2, varscan2
- VCAN | c.8380G>C p.E2794Q | Missense Mutation (SNP) | VAF 26/376 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.223); catalogued as rs1258524498, COSV54098501; called by muse, mutect2
- VPS13C | c.2662A>G p.T888A (on ENST00000644861 / NM_020821.3; = p.T845A on NM_017684.5) | Missense Mutation (SNP) | VAF 71/187 reads (38%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as COSV51126776; called by muse, mutect2, varscan2
- VPS16 | c.217G>T p.G73C | Missense Mutation (SNP) | VAF 77/255 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66792615; called by muse, mutect2, varscan2
- VPS25 | c.445C>G p.L149V | Missense Mutation (SNP) | VAF 6/102 reads (6%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.554); catalogued as COSV53820087, COSV99519538; called by muse, mutect2
- VPS35 | c.305G>C p.G102A | Missense Mutation (SNP) | VAF 27/193 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.966); catalogued as COSV54477333; called by muse, mutect2, varscan2
- VPS37C | c.532C>T p.P178S | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as rs757821185, COSV57108026; called by muse, mutect2, varscan2
- VSNL1 | c.531C>A p.S177R | Missense Mutation (SNP) | VAF 25/177 reads (14%) | SIFT tolerated (0.48); PolyPhen benign (0.019); catalogued as COSV54597763; called by muse, mutect2, varscan2
- VSTM2A | c.238G>T p.G80C | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.813); catalogued as COSV56492534; called by muse, mutect2, varscan2
- VSTM2A | c.372A>T p.L124F | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV56492547; called by muse, mutect2, varscan2
- VWA5A | c.1625+1G>C p.X542_splice | Splice Site (SNP) | VAF 23/227 reads (10%) | catalogued as COSV64412069; called by muse, mutect2
- VWF | c.2974G>T p.V992L | Missense Mutation (SNP) | VAF 23/143 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54613271; called by muse, mutect2, varscan2
- WARS2 | c.136A>G p.I46V | Missense Mutation (SNP) | VAF 77/436 reads (18%) | SIFT tolerated (0.38); PolyPhen benign (0.006); catalogued as COSV52476213; called by muse, mutect2, varscan2
- WDR27 | c.189G>T p.Q63H | Missense Mutation (SNP) | VAF 62/225 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV61205048; called by muse, mutect2, varscan2
- WDR36 | c.1610-1G>T p.X537_splice | Splice Site (SNP) | VAF 20/65 reads (31%) | catalogued as COSV72605091; called by muse, mutect2, varscan2
- WNK4 | c.2117A>C p.D706A | Missense Mutation (SNP) | VAF 8/168 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV55901944; called by muse, mutect2
- YARS2 | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 54/121 reads (45%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.007); catalogued as COSV61401423; called by muse, mutect2, varscan2
- YIPF7 | c.529G>T p.G177C | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60656114; called by muse, mutect2
- ZAN | c.2306C>A p.S769Y | Missense Mutation (SNP) | VAF 43/111 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.178); catalogued as COSV61805831; called by muse, mutect2, varscan2
- ZBED4 | c.424G>A p.E142K | Missense Mutation (SNP) | VAF 35/110 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV53464082; called by muse, mutect2, varscan2
- ZBTB21 | c.2044C>A p.L682I | Missense Mutation (SNP) | VAF 32/338 reads (9%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.963); catalogued as COSV60403299, COSV60404906; called by muse, mutect2
- ZC3H6 | c.2663C>G p.P888R | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.981); catalogued as COSV59666282; called by muse, mutect2, varscan2
- ZEB1 | c.2380C>T p.P794S | Missense Mutation (SNP) | VAF 36/159 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.084); catalogued as rs963030640, COSV100313658, COSV58037936; called by muse, mutect2, varscan2
- ZFHX4 | c.7613T>C p.M2538T | Missense Mutation (SNP) | VAF 48/361 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV50550614; called by muse, mutect2, varscan2
- ZFHX4 | c.9954G>C p.Q3318H | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.997); catalogued as COSV50550974; called by mutect2, varscan2
- ZFPM2 | c.2114A>G p.H705R | Missense Mutation (SNP) | VAF 39/113 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65872742; called by muse, mutect2, varscan2
- ZMYND11 | c.1307T>C p.V436A | Missense Mutation (SNP) | VAF 44/147 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.164); catalogued as COSV59076674; called by muse, mutect2, varscan2
- ZNF236 | c.5334C>G p.Y1778* | Nonsense Mutation (SNP) | VAF 12/134 reads (9%) | catalogued as COSV53483061, COSV53483402; called by muse, mutect2
- ZNF268 | c.1137G>T p.Q379H | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.735); catalogued as COSV99934759; called by muse, mutect2, varscan2
- ZNF268 | c.1138A>T p.K380* | Nonsense Mutation (SNP) | VAF 19/42 reads (45%) | catalogued as COSV99934762; called by muse, mutect2, varscan2
- ZNF285 | c.940A>T p.K314* | Nonsense Mutation (SNP) | VAF 28/229 reads (12%) | catalogued as COSV58408173; called by muse, mutect2, varscan2
- ZNF292 | c.2751G>T p.L917F | Missense Mutation (SNP) | VAF 47/144 reads (33%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.188); catalogued as COSV60536307; called by muse, mutect2, varscan2
- ZNF536 | c.2821C>A p.L941M | Missense Mutation (SNP) | VAF 20/520 reads (4%) | SIFT tolerated (0.29); PolyPhen benign (0.44); catalogued as COSV62819691; called by muse, mutect2
- ZNF592 | c.571G>C p.V191L | Missense Mutation (SNP) | VAF 93/277 reads (34%) | SIFT tolerated (0.28); PolyPhen benign (0.061); catalogued as COSV55435363; called by muse, mutect2, varscan2
- ZNF683 | c.1252C>G p.R418G (on ENST00000403843; = p.R398G on NM_173574.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 45/168 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV62873582, COSV62874562; called by muse, varscan2
- ZNF713 | c.198G>T p.E66D (on ENST00000633730 / NM_001366796.2; = p.E79D on NM_182633.3) | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV68887878; called by muse, mutect2, varscan2
- ZNF804B | c.1635G>T p.W545C | Missense Mutation (SNP) | VAF 45/154 reads (29%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.818); catalogued as COSV60818633; called by muse, mutect2, varscan2
- ZNF831 | c.4238C>G p.T1413S | Missense Mutation (SNP) | VAF 17/234 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.028); catalogued as COSV64037978; called by muse, mutect2
- ZP1 | c.307G>T p.V103L | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.333); catalogued as COSV53923401, COSV53923449; called by muse, mutect2, varscan2
- ZSCAN18 | c.527G>T p.G176V | Missense Mutation (SNP) | VAF 39/118 reads (33%) | SIFT tolerated (0.31); PolyPhen benign (0.009); catalogued as COSV53730179; called by muse, mutect2, varscan2
- ACVR2A | c.1310dup p.R438Efs*19 | Frame Shift Ins (INS) | VAF 47/186 reads (25%) | called by mutect2, varscan2
- AHNAK2 | c.16224del p.T5409Lfs*2 | Frame Shift Del (DEL) | VAF 25/99 reads (25%) | called by mutect2, pindel, varscan2
- AHNAK2 | c.5152del p.Q1718Rfs*5 | Frame Shift Del (DEL) | VAF 41/409 reads (10%) | called by mutect2, pindel, varscan2
- BIRC6 | c.4685_4693del p.E1562_P1565delinsA | In Frame Del (DEL) | VAF 40/336 reads (12%) | called by mutect2, pindel
- CSMD1 | c.3259del p.L1087Wfs*49 (on ENST00000520002; = p.L1086Wfs*49 on NM_033225.6) | Frame Shift Del (DEL) | VAF 17/136 reads (13%) | called by mutect2, pindel, varscan2
- CYP26A1 | c.641dup p.E215Rfs*119 | Frame Shift Ins (INS) | VAF 34/115 reads (30%) | called by pindel, varscan2
- FCGBP | c.814C>A p.Q272K | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.155); called by muse, mutect2, varscan2
- FNBP4 | c.343del p.D115Tfs*13 | Frame Shift Del (DEL) | VAF 41/199 reads (21%) | called by mutect2, pindel, varscan2
- FRG2C | c.703G>T p.V235F | Missense Mutation (SNP) | VAF 23/228 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.55); called by muse, mutect2
- HP1BP3 | c.1204G>T p.G402W | Missense Mutation (SNP) | VAF 16/160 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- IGHG1 | c.672G>C p.G224= | Splice Region (SNP) | VAF 86/301 reads (29%) | called by muse, varscan2
- IGKV1-33 | c.38T>A p.L13Q | Missense Mutation (SNP) | VAF 12/243 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2
- IGKV2D-24 | c.194C>A p.P65Q | Missense Mutation (SNP) | VAF 34/374 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.825); called by muse, mutect2
- LILRA6 | c.640C>G p.L214V | Missense Mutation (SNP) | VAF 21/148 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- LSP1 | c.905G>T p.G302V | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.494); called by muse, mutect2, varscan2
- MIXL1 | c.502del p.T168Rfs*4 | Frame Shift Del (DEL) | VAF 63/230 reads (27%) | called by mutect2, pindel, varscan2
- MUC5B | c.10047del p.S3350Pfs*13 | Frame Shift Del (DEL) | VAF 4/43 reads (9%) | called by pindel, varscan2
- OR2F2 | c.745del p.A249Pfs*25 | Frame Shift Del (DEL) | VAF 21/210 reads (10%) | called by mutect2, pindel
- PDZRN3 | c.252C>A p.Y84* | Nonsense Mutation (SNP) | VAF 3/23 reads (13%) | called by muse, mutect2
- PRH2 | c.362C>A p.P121H | Missense Mutation (SNP) | VAF 39/276 reads (14%) | SIFT tolerated, low confidence (0.18); PolyPhen possibly damaging (0.815); called by muse, mutect2, varscan2
- RSPH10B | c.184del p.Q62Kfs*17 | Frame Shift Del (DEL) | VAF 30/216 reads (14%) | called by mutect2, varscan2
- RTL4 | c.801_802delinsA p.P268Qfs*60 | Frame Shift Del (DEL) | VAF 14/75 reads (19%) | called by pindel, varscan2*
- SAMD9L | c.465del p.K155Nfs*2 | Frame Shift Del (DEL) | VAF 58/267 reads (22%) | called by mutect2, pindel, varscan2
- SLC6A9 | c.24dup p.M9Dfs*141 | Frame Shift Ins (INS) | VAF 76/689 reads (11%) | called by mutect2, pindel, varscan2
- SPATA31A3 | c.491A>C p.D164A | Missense Mutation (SNP) | VAF 98/693 reads (14%) | SIFT tolerated (0.41); PolyPhen benign (0.017); called by muse, mutect2
- STAB2 | c.5294dup p.L1765Ffs*29 | Frame Shift Ins (INS) | VAF 82/219 reads (37%) | called by mutect2, pindel, varscan2
- SUPT20HL2 | c.1044G>T p.W348C | Missense Mutation (SNP) | VAF 110/214 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.468); called by muse, mutect2, varscan2
- TLL2 | c.522dup p.S175Efs*7 | Frame Shift Ins (INS) | VAF 14/92 reads (15%) | called by mutect2, pindel, varscan2
- TRAV12-2 | c.42G>C p.Q14H | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- TRAV13-1 | c.301C>A p.P101T | Missense Mutation (SNP) | VAF 40/139 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.169); called by muse, mutect2, varscan2
- TRAV22 | c.88G>T p.D30Y | Missense Mutation (SNP) | VAF 36/138 reads (26%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.6); called by muse, mutect2, varscan2
- TRBV27 | c.251A>G p.K84R | Missense Mutation (SNP) | VAF 7/126 reads (6%) | SIFT tolerated (0.27); PolyPhen benign (0.003); called by muse, mutect2
- TRBV4-2 | c.53C>A p.P18H | Missense Mutation (SNP) | VAF 21/440 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- VPS13B | c.7232_7245del p.I2411Rfs*23 | Frame Shift Del (DEL) | VAF 22/164 reads (13%) | called by mutect2, pindel
- WASHC2C | c.3138G>T p.R1046S (on ENST00000336378; = p.R1025S on NM_015262.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 36/319 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- WDR35 | c.2616_2617del p.C872* (on ENST00000345530 / NM_001006657.2; = p.C861* on NM_020779.4) | Nonsense Mutation (DEL) | VAF 33/166 reads (20%) | called by pindel, varscan2
- ZFHX3 | c.536dup p.K180Qfs*30 | Frame Shift Ins (INS) | VAF 9/85 reads (11%) | called by mutect2, pindel
- ADCY8 | c.3126C>A p.A1042= | Silent (SNP) | VAF 43/249 reads (17%) | catalogued as COSV53898358, COSV53911273; called by muse, mutect2, varscan2
- ADPRHL1 | c.72G>A p.K24= | Silent (SNP) | VAF 17/102 reads (17%) | catalogued as COSV60260782; called by muse, mutect2, varscan2
- AFF1 | c.1716G>T p.R572= | Silent (SNP) | VAF 7/27 reads (26%) | catalogued as COSV100320262; called by muse, mutect2, varscan2
- AGBL1 | c.2272C>A p.R758= | Silent (SNP) | VAF 36/123 reads (29%) | catalogued as COSV66850612, COSV66852202; called by muse, mutect2, varscan2
- ALDH1L1 | c.744G>C p.T248= | Silent (SNP) | VAF 43/192 reads (22%) | catalogued as COSV56411317, COSV56415451; called by muse, mutect2, varscan2
- ANO6 | c.2056C>T p.L686= | Silent (SNP) | VAF 49/129 reads (38%) | catalogued as COSV57657696; called by muse, mutect2, varscan2
- APOB | c.3144C>A p.T1048= | Silent (SNP) | VAF 19/130 reads (15%) | catalogued as COSV51925700; called by muse, mutect2, varscan2
- ARHGAP6 | c.1761C>A p.I587= | Silent (SNP) | VAF 46/125 reads (37%) | catalogued as COSV57292426, COSV57304386; called by muse, mutect2, varscan2
- ARHGEF28 | c.2484A>T p.A828= | Silent (SNP) | VAF 38/245 reads (16%) | catalogued as COSV55248680; called by muse, mutect2, varscan2
- ASB10 | c.672G>T p.R224= (on ENST00000420175 / NM_001142459.2; = p.R209= on NM_080871.4) | Silent (SNP) | VAF 26/83 reads (31%) | catalogued as COSV51994634, COSV51997282; called by muse, mutect2, varscan2
- ASB15 | c.324C>A p.T108= | Silent (SNP) | VAF 69/239 reads (29%) | catalogued as COSV99306298; called by muse, mutect2, varscan2
- BBS9 | c.2262G>A p.A754= (on ENST00000242067 / NM_001348036.1; = p.A714= on NM_014451.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 14/177 reads (8%) | catalogued as rs751886707, COSV54158541; called by muse, mutect2
- BEGAIN | c.609C>T p.S203= | Silent (SNP) | VAF 6/33 reads (18%) | catalogued as rs773033317, COSV62068145; called by muse, mutect2, varscan2
- BEND2 | c.1188C>A p.G396= | Silent (SNP) | VAF 61/155 reads (39%) | catalogued as COSV66215217, COSV66215543; called by muse, mutect2, varscan2
- BLK | c.300C>A p.L100= | Silent (SNP) | VAF 4/23 reads (17%) | catalogued as rs745823355, COSV99376900; called by muse, mutect2, varscan2
- BNIP2 | c.765A>T p.T255= | Silent (SNP) | VAF 35/124 reads (28%) | catalogued as COSV51105222; called by muse, mutect2, varscan2
- BOD1L1 | c.2568T>C p.G856= | Silent (SNP) | VAF 10/100 reads (10%) | catalogued as COSV50007350; called by muse, mutect2, varscan2
- BPIFB1 | c.93C>T p.L31= | Silent (SNP) | VAF 30/175 reads (17%) | catalogued as rs766101557, COSV53605360; called by muse, mutect2, varscan2
- BRINP3 | c.396G>T p.G132= | Silent (SNP) | VAF 36/255 reads (14%) | catalogued as COSV66515015; called by muse, mutect2, varscan2
- C1QB | c.141C>A p.P47= | Silent (SNP) | VAF 17/56 reads (30%) | catalogued as COSV59245084; called by muse, mutect2, varscan2
- C9orf131 | c.3216C>A p.P1072= | Silent (SNP) | VAF 92/361 reads (25%) | catalogued as COSV56609850; called by muse, mutect2, varscan2
- C9orf72 | c.951G>A p.Q317= | Silent (SNP) | VAF 30/376 reads (8%) | catalogued as rs758101832, COSV66154527, COSV66154584; called by muse, mutect2
- CALHM2 | c.9C>A p.A3= | Silent (SNP) | VAF 66/188 reads (35%) | catalogued as COSV53294521; called by muse, mutect2, varscan2
- CD109 | c.294A>T p.A98= | Silent (SNP) | VAF 70/190 reads (37%) | catalogued as COSV54646080; called by muse, mutect2, varscan2
- CD22 | c.2220C>A p.A740= | Silent (SNP) | VAF 42/109 reads (39%) | catalogued as rs1389878115, COSV50049863, COSV50055705; called by muse, mutect2, varscan2
191 further variants in this file (0 protein-altering or splice-affecting, 174 silent, 17 other) are not listed here.
